Somatic mutation profile of tumor specimen C3N-04293-02 (aliquot CPT0244700009) from CPTAC case C3N-04293, project CPTAC-3 (Skin — Nevi and Melanomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IV; Age at diagnosis: 75.7 years (27,654 days).
Specimen C3N-04293-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Biospecimen anatomic site: Lymph Node; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 16233c32-9137-4e31-91f6-62ebf8f910d1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-04293-31 (Blood Derived Normal), aliquot CPT0244720002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/316e884d-5a77-4b70-ac6a-e8b227c4264c

The open-access MAF lists 981 somatic variants for this specimen: 616 protein-altering or splice-affecting, 319 silent, 46 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 566, Silent 319, Nonsense Mutation 32, Intron 30, Splice Region 13, 3'UTR 7, RNA 4, 5'Flank 3, 5'UTR 2, Translation Start Site 1, Splice Site 1, In Frame Del 1.

Variants (750 of 981; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 459/661 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- BRAF | c.1918G>A p.V640M (on ENST00000288602 / NM_001374244.1; = p.V600M on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 414/604 reads (69%) | SIFT deleterious (0); PolyPhen possibly damaging (0.737); catalogued as rs121913378, COSV56066607, COSV56075762, COSV56124012, COSV56152883; ClinVar: likely pathogenic / pathogenic; called by muse, varscan2
- CTNNB1 | c.101G>T p.G34V | Missense Mutation (SNP) | VAF 170/529 reads (32%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28931589, COSV62687976, COSV62688267, COSV62692205; ClinVar: likely pathogenic / uncertain significance / pathogenic; called by muse, mutect2, varscan2
- EZH2 | c.1921T>A p.Y641N (on ENST00000460911 / NM_001203247.2; = p.Y646N on NM_004456.5) | Missense Mutation (SNP) | VAF 236/659 reads (36%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.949); catalogued as rs267601395, COSV57445793, COSV57445823, COSV57462051; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCE1 | c.442C>G p.R148G | Missense Mutation (SNP) | VAF 80/226 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as COSV56848285; called by muse, mutect2, varscan2
- ACSM6 | c.197G>A p.G66E | Missense Mutation (SNP) | VAF 62/204 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as rs1253693135; called by muse, varscan2
- ACTG2 | c.898C>T p.L300F | Missense Mutation (SNP) | VAF 133/424 reads (31%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.917); catalogued as rs1194901451; called by muse, mutect2, varscan2
- ADAM29 | c.1451G>A p.G484E | Missense Mutation (SNP) | VAF 196/440 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63661589; called by muse, mutect2, varscan2
- ADAMDEC1 | c.950G>A p.R317Q | Missense Mutation (SNP) | VAF 142/412 reads (34%) | SIFT tolerated (0.61); PolyPhen benign (0.062); catalogued as rs767110341; called by muse, mutect2, varscan2
- ADAMTS20 | c.3377G>A p.R1126K | Missense Mutation (SNP) | VAF 88/238 reads (37%) | SIFT tolerated (0.3); PolyPhen benign (0.011); catalogued as rs867059767, COSV67139126; called by muse, mutect2, varscan2
- ADCY8 | c.1292C>T p.S431F | Missense Mutation (SNP) | VAF 90/310 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV53927119, COSV99650847; called by muse, mutect2, varscan2
- ADCY8 | c.1210C>T p.R404W | Missense Mutation (SNP) | VAF 96/332 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.48); catalogued as COSV53903311; called by muse, mutect2, varscan2
- ADGRV1 | c.3739G>A p.E1247K | Missense Mutation (SNP) | VAF 146/439 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.011); catalogued as COSV101315544; called by muse, mutect2, varscan2
- AGAP3 | c.920C>T p.P307L (on ENST00000622464; = p.P343L on NM_031946.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 233/1663 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.649); catalogued as COSV100103846, COSV58993908; called by muse, mutect2, varscan2
- AGBL3 | c.1148G>A p.G383E | Missense Mutation (SNP) | VAF 171/1128 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV51958301; called by muse, mutect2, varscan2
- AIFM3 | c.973C>T p.R325C | Missense Mutation (SNP) | VAF 155/712 reads (22%) | SIFT tolerated (0.05); PolyPhen benign (0.055); catalogued as rs968679291, COSV100104139; called by muse, mutect2, varscan2
- AKAP3 | c.352G>A p.G118R | Missense Mutation (SNP) | VAF 256/510 reads (50%) | SIFT tolerated (0.48); PolyPhen benign (0.007); catalogued as rs771641749, COSV57413492; called by muse, mutect2, varscan2
- ALDH5A1 | c.842C>T p.S281F | Missense Mutation (SNP) | VAF 92/301 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs267600900, COSV62372745; called by muse, mutect2, varscan2
- ALPK3 | c.2860C>T p.P954S | Missense Mutation (SNP) | VAF 164/465 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.108); catalogued as rs773148900; called by muse, mutect2, varscan2
- ANKRD17 | c.6389C>T p.P2130L | Missense Mutation (SNP) | VAF 141/439 reads (32%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.025); catalogued as rs778751458; called by muse, mutect2, varscan2
- ANKRD30A | c.2770G>A p.D924N (on ENST00000611781; = p.D868N on NM_052997.2) | Missense Mutation (SNP) | VAF 12/92 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.419); catalogued as COSV64603707; called by muse, mutect2, varscan2
- ANO4 | c.827G>A p.G276E (on ENST00000392977 / NM_001286615.2; = p.G241E on NM_178826.4) | Missense Mutation (SNP) | VAF 55/231 reads (24%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.974); catalogued as COSV54612988; called by muse, mutect2, varscan2
- APBB2 | c.1585C>T p.R529* (on ENST00000295974 / NM_001166050.2; = p.R530* on NM_004307.2) | Nonsense Mutation (SNP) | VAF 97/321 reads (30%) | catalogued as rs757146916, COSV55946364; called by muse, mutect2, varscan2
- APOB | c.7654G>A p.D2552N | Missense Mutation (SNP) | VAF 128/420 reads (30%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as COSV51947058; called by muse, mutect2, varscan2
- APOBEC3B | c.820A>G p.R274G | Missense Mutation (SNP) | VAF 143/1229 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.385); catalogued as rs769889025; called by muse, mutect2, varscan2
- APOBR | c.1660G>A p.G554R (on ENST00000431282; = p.G563R on NM_018690.4) | Missense Mutation (SNP) | VAF 166/519 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.005); catalogued as rs1567268393; called by muse, mutect2, varscan2
- ARHGAP6 | c.602G>A p.W201* | Nonsense Mutation (SNP) | VAF 105/164 reads (64%) | catalogued as COSV57292864; called by muse, mutect2, varscan2
- ASXL3 | c.2107G>A p.E703K | Missense Mutation (SNP) | VAF 129/441 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as rs768555015; called by muse, mutect2, varscan2
- ATCAY | c.976G>A p.E326K | Missense Mutation (SNP) | VAF 130/409 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.039); catalogued as COSV100008577; called by muse, mutect2, varscan2
- ATP7B | c.2816G>A p.W939* | Nonsense Mutation (SNP) | VAF 224/347 reads (65%) | catalogued as CM123059; called by muse, varscan2
- ATXN1 | c.1123C>T p.P375S | Missense Mutation (SNP) | VAF 200/589 reads (34%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55222114; called by muse, mutect2, varscan2
- BCAS3 | c.2414C>T p.S805L (on ENST00000390652 / NM_001353144.2; = p.S790L on NM_017679.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 115/363 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.154); catalogued as COSV66775346; called by muse, mutect2, varscan2
- BDKRB1 | c.829C>T p.Q277* | Nonsense Mutation (SNP) | VAF 196/500 reads (39%) | catalogued as rs1371823615; called by muse, mutect2, varscan2
- BHMG1 | c.208C>T p.P70S | Missense Mutation (SNP) | VAF 110/374 reads (29%) | SIFT tolerated, low confidence (0.75); PolyPhen benign (0.013); catalogued as rs1568555078; called by muse, mutect2, varscan2
- BMP10 | c.862G>A p.D288N | Missense Mutation (SNP) | VAF 179/533 reads (34%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as COSV54895333; called by muse, mutect2, varscan2
- BRINP3 | c.1579C>T p.P527S | Missense Mutation (SNP) | VAF 142/575 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs761165872; called by muse, mutect2, varscan2
- BTNL8 | c.1198C>T p.P400S | Missense Mutation (SNP) | VAF 150/205 reads (73%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.783); catalogued as rs1233522289, COSV51460687; called by muse, mutect2, varscan2
- BVES | c.958C>T p.H320Y | Missense Mutation (SNP) | VAF 101/295 reads (34%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV58946553; called by muse, mutect2, varscan2
- C6 | c.1774C>T p.P592S | Missense Mutation (SNP) | VAF 123/430 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54706697, COSV54710729; called by muse, mutect2, varscan2
- C8A | c.505G>A p.D169N | Missense Mutation (SNP) | VAF 96/344 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs940831429, COSV63483165; called by muse, mutect2, varscan2
- CACNG2 | c.767G>A p.G256D | Missense Mutation (SNP) | VAF 215/384 reads (56%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); catalogued as rs759221759; called by muse, mutect2, varscan2
- CADM1 | c.1103C>T p.S368L | Missense Mutation (SNP) | VAF 91/186 reads (49%) | SIFT tolerated (0.16); PolyPhen benign (0.107); catalogued as rs267602705, COSV100523215; called by muse, mutect2, varscan2
- CADPS | c.3137C>T p.S1046L | Missense Mutation (SNP) | VAF 125/387 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as rs373178609; called by muse, mutect2, varscan2
- CALB1 | c.431C>T p.A144V | Missense Mutation (SNP) | VAF 68/274 reads (25%) | SIFT tolerated (0.25); PolyPhen benign (0.038); catalogued as rs1297804715; called by muse, mutect2, varscan2
- CAMTA1 | c.1183C>T p.Q395* | Nonsense Mutation (SNP) | VAF 46/396 reads (12%) | catalogued as COSV100350833; called by muse, mutect2, varscan2
- CAPSL | c.232G>A p.E78K | Missense Mutation (SNP) | VAF 158/484 reads (33%) | SIFT tolerated (0.13); PolyPhen benign (0.088); catalogued as COSV68438786; called by muse, mutect2
- CARMIL3 | c.3521G>A p.R1174Q | Missense Mutation (SNP) | VAF 105/312 reads (34%) | SIFT tolerated (0.79); PolyPhen benign (0.081); catalogued as rs779112630; called by muse, mutect2, varscan2
- CCDC172 | c.331G>A p.E111K | Missense Mutation (SNP) | VAF 37/147 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as COSV60938410; called by muse, mutect2, varscan2
- CCDC60 | c.1015G>A p.E339K | Missense Mutation (SNP) | VAF 120/380 reads (32%) | SIFT tolerated (0.37); PolyPhen benign (0.167); catalogued as rs1297066120, COSV59540844; called by muse, mutect2, varscan2
- CD177 | c.500G>A p.G167E | Missense Mutation (SNP) | VAF 55/190 reads (29%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.781); catalogued as rs775597706, COSV65122627; called by muse, mutect2, varscan2
- CD1A | c.371G>A p.G124E | Missense Mutation (SNP) | VAF 110/484 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.81); catalogued as COSV56860318, COSV99192402; called by muse, mutect2, varscan2
- CDH6 | c.1381A>G p.T461A | Missense Mutation (SNP) | VAF 92/225 reads (41%) | SIFT tolerated (0.15); PolyPhen benign (0.012); catalogued as rs746641388; called by muse, mutect2, varscan2
- CENPS-CORT | c.51G>A p.Q17= | Splice Region (SNP) | VAF 76/266 reads (29%) | catalogued as rs1273864809; called by muse, mutect2, varscan2
- CFAP65 | c.3754G>A p.E1252K | Missense Mutation (SNP) | VAF 91/316 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.813); catalogued as COSV58563528, COSV58567614; called by muse, mutect2, varscan2
- CFH | c.3611G>A p.G1204E | Missense Mutation (SNP) | VAF 138/644 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.733); catalogued as CM070670, COSV66408650; called by muse, mutect2, varscan2
- CFHR5 | c.53G>A p.G18E | Missense Mutation (SNP) | VAF 161/354 reads (45%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.955); catalogued as rs764524706, COSV56817589; called by muse, mutect2, varscan2
- CHD7 | c.818C>T p.P273L | Missense Mutation (SNP) | VAF 145/487 reads (30%) | SIFT tolerated, low confidence (0.43); PolyPhen possibly damaging (0.57); catalogued as rs762771594; called by muse, mutect2, varscan2
- CLSTN2 | c.881C>T p.S294F | Missense Mutation (SNP) | VAF 152/455 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.005); catalogued as rs267599629; called by muse, mutect2, varscan2
- CMYA5 | c.3208C>T p.P1070S | Missense Mutation (SNP) | VAF 147/399 reads (37%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.645); catalogued as COSV71410459; called by muse, mutect2, varscan2
- CNGB3 | c.143G>A p.G48D | Missense Mutation (SNP) | VAF 74/242 reads (31%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as rs766600503; called by muse, mutect2, varscan2
- COL6A5 | c.4888G>A p.G1630R | Missense Mutation (SNP) | VAF 105/325 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs759100126, COSV55219899; called by muse, mutect2, varscan2
- CORIN | c.1392G>A p.M464I | Missense Mutation (SNP) | VAF 102/340 reads (30%) | SIFT tolerated (0.13); PolyPhen benign (0.018); catalogued as COSV56694294; called by muse, mutect2, varscan2
- CPZ | c.1814G>A p.G605E (on ENST00000360986 / NM_001014447.3; = p.G594E on NM_003652.3) | Missense Mutation (SNP) | VAF 161/488 reads (33%) | SIFT tolerated (0.99); PolyPhen benign (0.003); catalogued as COSV59926114; called by muse, mutect2, varscan2
- CRB1 | c.1676C>T p.S559F | Missense Mutation (SNP) | VAF 106/506 reads (21%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.936); catalogued as COSV66330452; called by muse, mutect2, varscan2
- CSMD3 | c.4684G>A p.G1562R (on ENST00000297405 / NM_001363185.1; = p.G1458R on NM_052900.3) | Missense Mutation (SNP) | VAF 146/419 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1480046849, COSV52173447, COSV52210514; called by muse, mutect2, varscan2
- CYP21A2 | c.973G>A p.E325K | Missense Mutation (SNP) | VAF 140/526 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.041); catalogued as rs150804717; called by muse, mutect2, varscan2
- DCAF1 | c.458G>A p.G153D | Missense Mutation (SNP) | VAF 99/329 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.011); catalogued as rs782172319; called by muse, mutect2, varscan2
- DDX60L | c.4756C>T p.R1586* | Nonsense Mutation (SNP) | VAF 76/316 reads (24%) | catalogued as rs781529479; called by muse, mutect2, varscan2
- DEUP1 | c.383T>C p.L128P | Missense Mutation (SNP) | VAF 108/202 reads (53%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as COSV53212580; called by muse, mutect2, varscan2
- DGLUCY | c.1691C>T p.S564L | Missense Mutation (SNP) | VAF 88/260 reads (34%) | SIFT tolerated (0.05); PolyPhen benign (0.293); catalogued as rs368952726; called by muse, mutect2, varscan2
- DNAH11 | c.1489G>A p.G497R | Missense Mutation (SNP) | VAF 147/643 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV60984748; called by muse, mutect2, varscan2
- DNAH14 | c.5380C>T p.P1794S (on ENST00000445597; = p.P2199S on NM_001367479.1) | Missense Mutation (SNP) | VAF 117/463 reads (25%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as COSV59895761; called by muse, mutect2, varscan2
- DNAH3 | c.1527G>A p.W509* | Nonsense Mutation (SNP) | VAF 139/483 reads (29%) | catalogued as COSV54524775; called by muse, mutect2, varscan2
- DNAH5 | c.8303C>T p.P2768L | Missense Mutation (SNP) | VAF 140/405 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.111); catalogued as rs151040029, COSV54246933; called by muse, mutect2, varscan2
- DNAH5 | c.6038G>A p.R2013Q | Missense Mutation (SNP) | VAF 114/381 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as rs754169445, COSV54246459; called by muse, mutect2, varscan2
- DNAJB7 | c.311G>A p.R104K | Missense Mutation (SNP) | VAF 117/694 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV53421935; called by muse, mutect2, varscan2
- DNAJC2 | c.289C>T p.H97Y | Missense Mutation (SNP) | VAF 636/886 reads (72%) | SIFT tolerated (0.54); PolyPhen benign (0.285); catalogued as rs779171668; called by muse, mutect2, varscan2
- DOCK3 | c.829G>A p.D277N | Missense Mutation (SNP) | VAF 88/270 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV56549182; called by muse, mutect2, varscan2
- DPY19L2 | c.2036G>A p.R679Q | Missense Mutation (SNP) | VAF 50/170 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs202000576, COSV61044435; called by muse, mutect2, varscan2
- DSC2 | c.653C>T p.P218L | Missense Mutation (SNP) | VAF 61/246 reads (25%) | SIFT tolerated (0.19); PolyPhen benign (0.082); catalogued as rs756441863; called by muse, mutect2, varscan2
- DSPP | c.3517G>A p.D1173N | Missense Mutation (SNP) | VAF 236/744 reads (32%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.157); catalogued as rs748970376, COSV99217258; called by muse, varscan2
- DVL1 | c.2008C>T p.P670S (on ENST00000378888 / NM_001330311.2; = p.P645S on NM_004421.3) | Missense Mutation (SNP) | VAF 210/648 reads (32%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.977); catalogued as rs779009859; called by muse, mutect2, varscan2
- DYNC2I2 | c.244C>T p.H82Y | Missense Mutation (SNP) | VAF 176/526 reads (33%) | SIFT tolerated (0.75); PolyPhen benign (0.043); catalogued as COSV65549690; called by muse, mutect2, varscan2
- DZANK1 | c.1373A>G p.Q458R (on ENST00000262547 / NM_001099407.1; = p.Q265R on NM_018152.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 271/568 reads (48%) | SIFT tolerated (0.22); PolyPhen benign (0.009); catalogued as rs1006501186; called by muse, mutect2, varscan2
- EPS8L3 | c.969C>T p.F323= | Splice Region (SNP) | VAF 132/329 reads (40%) | catalogued as rs1411263430, COSV62610025; called by muse, mutect2, varscan2
- EXD3 | c.2449C>T p.P817S | Missense Mutation (SNP) | VAF 220/609 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.922); catalogued as rs542445427; called by muse, mutect2, varscan2
- F8 | c.2768T>C p.L923S | Missense Mutation (SNP) | VAF 137/225 reads (61%) | SIFT tolerated (0.3); PolyPhen benign (0.005); catalogued as CM106050; called by muse, mutect2, varscan2
- F8 | c.1787C>T p.S596F | Missense Mutation (SNP) | VAF 134/210 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as CM1510592; called by muse, mutect2, varscan2
- FAM135B | c.3850G>A p.D1284N | Missense Mutation (SNP) | VAF 87/264 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52726361; called by muse, mutect2, varscan2
- FAM169A | c.647C>T p.P216L | Missense Mutation (SNP) | VAF 79/249 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1311899244; called by muse, mutect2, varscan2
- FAM20B | c.1171G>A p.D391N | Missense Mutation (SNP) | VAF 126/577 reads (22%) | SIFT tolerated (0.24); PolyPhen benign (0.082); catalogued as rs374181238; called by muse, mutect2, varscan2
- FASLG | c.424G>A p.E142K | Missense Mutation (SNP) | VAF 95/416 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as rs1208822346; called by muse, mutect2, varscan2
- FAT4 | c.8122G>A p.E2708K | Missense Mutation (SNP) | VAF 108/380 reads (28%) | SIFT tolerated (0.58); PolyPhen benign (0.106); catalogued as rs865926471, COSV100629593; called by muse, mutect2, varscan2
- FBXO24 | c.5G>A p.G2D | Missense Mutation (SNP) | VAF 408/1045 reads (39%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as rs368371879; called by muse, mutect2, varscan2
- FBXO24 | c.1711G>A p.G571S (on ENST00000241071 / NM_033506.3; = p.G609S on NM_012172.5) | Missense Mutation (SNP) | VAF 992/1339 reads (74%) | SIFT tolerated, low confidence (0.67); PolyPhen benign (0.003); catalogued as rs371121692; called by muse, mutect2, varscan2
- FBXW10 | c.872-3C>T | Splice Region (SNP) | VAF 201/662 reads (30%) | catalogued as rs777652149; called by muse, mutect2
- FCRL5 | c.2633G>A p.G878E | Missense Mutation (SNP) | VAF 280/522 reads (54%) | SIFT tolerated (0.15); PolyPhen benign (0.391); catalogued as rs780208492, COSV100709136; called by muse, mutect2, varscan2
- FNDC1 | c.2687C>T p.S896F | Missense Mutation (SNP) | VAF 157/461 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.029); catalogued as rs1346088399; called by muse, mutect2, varscan2
- FOLH1 | c.1491G>A p.W497* | Nonsense Mutation (SNP) | VAF 69/165 reads (42%) | catalogued as rs1429385037, COSV99922502; called by muse, mutect2, varscan2
- FZD7 | c.1720G>A p.V574I | Missense Mutation (SNP) | VAF 72/229 reads (31%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.224); catalogued as rs974234940; called by muse, mutect2, varscan2
- GAA | c.469C>T p.P157S | Missense Mutation (SNP) | VAF 188/561 reads (34%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as rs1360565713, COSV100163509; called by muse, mutect2, varscan2
- GDAP2 | c.529C>T p.P177S | Missense Mutation (SNP) | VAF 86/276 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs933958202; called by muse, mutect2, varscan2
- GIMAP1 | c.130G>A p.G44R | Missense Mutation (SNP) | VAF 152/1203 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV56189880; called by muse, mutect2, varscan2
- GOLGA6L6 | c.367C>T p.L123F | Missense Mutation (SNP) | VAF 27/322 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1366981238; called by muse, mutect2, varscan2
- GPR135 | c.1210G>A p.E404K | Missense Mutation (SNP) | VAF 175/569 reads (31%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.815); catalogued as rs757143531; called by muse, mutect2, varscan2
- GPR20 | c.886G>A p.V296I | Missense Mutation (SNP) | VAF 259/738 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as rs201215470, COSV66684668; called by muse, mutect2, varscan2
- GPR27 | c.946C>T p.P316S | Missense Mutation (SNP) | VAF 234/640 reads (37%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.869); catalogued as rs746786041; called by muse, varscan2
- GRIA1 | c.1805G>A p.G602E | Missense Mutation (SNP) | VAF 83/258 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53588694; called by muse, mutect2, varscan2
- GRIN2A | c.2063G>A p.G688E | Missense Mutation (SNP) | VAF 158/455 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58021069; called by muse, mutect2, varscan2
- GRIN2A | c.1029G>A p.W343* | Nonsense Mutation (SNP) | VAF 74/272 reads (27%) | catalogued as rs144703143, COSV58053467; called by muse, mutect2, varscan2
- GRM3 | c.461C>T p.S154F | Missense Mutation (SNP) | VAF 77/581 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV64469390; called by muse, mutect2, varscan2
- GUCY2C | c.1267G>A p.D423N | Missense Mutation (SNP) | VAF 197/373 reads (53%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.698); catalogued as COSV99664086; called by muse, mutect2, varscan2
- HDAC7 | c.1195C>T p.R399W (on ENST00000427332; = p.R438W on NM_015401.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 125/446 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs139027593; called by muse, mutect2, varscan2
- HELZ | c.4066C>T p.P1356S | Missense Mutation (SNP) | VAF 190/526 reads (36%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.3); catalogued as rs749763290, COSV100698702; called by muse, mutect2, varscan2
- HHLA1 | c.989C>T p.S330L | Missense Mutation (SNP) | VAF 81/279 reads (29%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs369879360, COSV51841488; called by muse, mutect2, varscan2
- HIRA | c.2872A>T p.I958L | Missense Mutation (SNP) | VAF 129/316 reads (41%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1556010848; called by muse, mutect2, varscan2
- HIVEP2 | c.1543G>A p.E515K | Missense Mutation (SNP) | VAF 141/416 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as rs137998676, COSV50074114; called by muse, mutect2, varscan2
- HNRNPDL | c.47C>T p.P16L | Missense Mutation (SNP) | VAF 131/407 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.908); catalogued as rs1165100198; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- HPS1 | c.833C>T p.S278F | Missense Mutation (SNP) | VAF 152/514 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.446); catalogued as rs996787797; called by muse, mutect2
- HSF1 | c.710C>T p.S237L | Missense Mutation (SNP) | VAF 133/369 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as rs1206813299, COSV60048527; called by muse, mutect2, varscan2
- HTR1A | c.619C>T p.P207S | Missense Mutation (SNP) | VAF 129/429 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1248736722, COSV60500863; called by muse, mutect2, varscan2
- IQGAP2 | c.2065G>A p.E689K | Missense Mutation (SNP) | VAF 84/286 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1245336379; called by muse, mutect2, varscan2
- ITPRID1 | c.873G>A p.W291* | Nonsense Mutation (SNP) | VAF 103/495 reads (21%) | catalogued as rs1291774151; called by muse, mutect2, varscan2
- JAML | c.613C>T p.R205C (on ENST00000356289 / NM_001098526.2; = p.R195C on NM_153206.3) | Missense Mutation (SNP) | VAF 128/262 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs753962552, COSV52630227; called by muse, mutect2, varscan2
- KCNB2 | c.377G>A p.W126* | Nonsense Mutation (SNP) | VAF 137/427 reads (32%) | catalogued as COSV73049980; called by muse, mutect2, varscan2
- KCNH5 | c.2620C>T p.R874C | Missense Mutation (SNP) | VAF 107/373 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.971); catalogued as rs754436628, COSV59753363; called by muse, mutect2, varscan2
- KCP | c.3877G>A p.D1293N (on ENST00000620378; = p.D1417N on NM_001366122.1) | Missense Mutation (SNP) | VAF 892/1151 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1411134993; called by muse, mutect2, varscan2
- KDR | c.908G>A p.G303E | Missense Mutation (SNP) | VAF 139/419 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55776134; called by muse, mutect2, varscan2
- KIAA0408 | c.824G>A p.R275Q | Missense Mutation (SNP) | VAF 131/362 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs770650380, COSV64105143; called by muse, mutect2, varscan2
- KIF5A | c.1183G>A p.E395K | Missense Mutation (SNP) | VAF 160/469 reads (34%) | SIFT tolerated (0.35); PolyPhen benign (0.028); catalogued as COSV54058977; called by muse, mutect2, varscan2
- KLRK1 | c.191G>A p.G64E | Missense Mutation (SNP) | VAF 108/373 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as rs753001440, COSV53698178; called by muse, mutect2, varscan2
- KRTAP29-1 | c.914C>T p.S305L | Missense Mutation (SNP) | VAF 233/673 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.598); catalogued as rs1488669958; called by muse, mutect2, varscan2
- LAMA3 | c.9275G>A p.G3092E (on ENST00000313654 / NM_198129.4; = p.G1483E on NM_000227.6) | Missense Mutation (SNP) | VAF 136/452 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as rs1383006206, COSV52536031; called by muse, mutect2, varscan2
- LCE2B | c.52C>T p.P18S | Missense Mutation (SNP) | VAF 282/609 reads (46%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.932); catalogued as COSV64227608; called by muse, mutect2, varscan2
- LCOR | c.775C>T p.R259* | Nonsense Mutation (SNP) | VAF 163/423 reads (39%) | catalogued as COSV63630525; called by muse, mutect2, varscan2
- LGSN | c.904T>C p.F302L | Missense Mutation (SNP) | VAF 123/380 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.489); catalogued as rs1228582960; called by muse, mutect2, varscan2
- LMTK3 | c.1646C>T p.P549L | Missense Mutation (SNP) | VAF 124/390 reads (32%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.021); catalogued as rs1474407754; called by muse, mutect2, varscan2
- LONP1 | c.152C>T p.P51L | Missense Mutation (SNP) | VAF 191/534 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs759451701; called by muse, mutect2, varscan2
- LRP1B | c.2689C>T p.R897C | Missense Mutation (SNP) | VAF 112/304 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs766736610, COSV63341701; called by muse, mutect2, varscan2
- LTBP1 | c.4894G>A p.E1632K (on ENST00000404816 / NM_206943.4; = p.E1306K on NM_000627.4) | Missense Mutation (SNP) | VAF 106/347 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs866380373; called by muse, mutect2, varscan2
- MACC1 | c.1592C>T p.P531L | Missense Mutation (SNP) | VAF 115/542 reads (21%) | SIFT tolerated (0.3); PolyPhen benign (0.007); catalogued as rs781045799; called by muse, mutect2, varscan2
- MALRD1 | c.556G>A p.E186K | Missense Mutation (SNP) | VAF 118/349 reads (34%) | SIFT tolerated (0.87); PolyPhen benign (0.11); catalogued as rs1434628137; called by muse, mutect2, varscan2
- MALRD1 | c.6157G>A p.G2053R | Missense Mutation (SNP) | VAF 94/292 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1289091687; called by muse, mutect2, varscan2
- MAP3K5 | c.2717C>T p.S906F | Missense Mutation (SNP) | VAF 106/340 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV62886883; called by muse, mutect2, varscan2
- MBD3L5 | c.622G>A p.G208R | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.132); catalogued as rs4031064; called by muse, mutect2
- MC2R | c.676G>A p.G226R | Missense Mutation (SNP) | VAF 183/357 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs761911005, CM160060; called by muse, mutect2, varscan2
- MCF2L | c.2399C>T p.S800F (on ENST00000375608; = p.S768F on NM_024979.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 252/355 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV56177328; called by muse, mutect2, varscan2
- MIB2 | c.4G>A p.A2T | Missense Mutation (SNP) | VAF 95/286 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs1278428164; called by muse, mutect2, varscan2
- MIDEAS | c.2162C>T p.P721L | Missense Mutation (SNP) | VAF 133/423 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54095576; called by muse, mutect2, varscan2
- MISP | c.736C>T p.P246S | Missense Mutation (SNP) | VAF 184/529 reads (35%) | SIFT tolerated (0.3); PolyPhen benign (0.031); catalogued as COSV53121970; called by muse, mutect2, varscan2
- MMP14 | c.323G>A p.R108Q | Missense Mutation (SNP) | VAF 152/441 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as COSV61287995; called by muse, mutect2, varscan2
- MOK | c.718C>T p.P240S | Missense Mutation (SNP) | VAF 91/255 reads (36%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.854); catalogued as COSV99513074; called by muse, mutect2, varscan2
- MOV10L1 | c.1216C>T p.P406S | Missense Mutation (SNP) | VAF 196/338 reads (58%) | SIFT tolerated (0.17); PolyPhen benign (0.062); catalogued as COSV53169503; called by muse, mutect2, varscan2
- MPG | c.527G>A p.G176E | Missense Mutation (SNP) | VAF 97/305 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs781452593; called by muse, mutect2, varscan2
- MTUS2 | c.874G>A p.E292K | Missense Mutation (SNP) | VAF 127/377 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.121); catalogued as rs745785312, COSV70913639; called by muse, mutect2, varscan2
- MUC16 | c.2738C>T p.S913L | Missense Mutation (SNP) | VAF 112/364 reads (31%) | SIFT tolerated, low confidence (0.13); PolyPhen probably damaging (0.958); catalogued as rs1568214250; called by muse, mutect2, varscan2
- MUC17 | c.1118C>T p.S373L | Missense Mutation (SNP) | VAF 801/1071 reads (75%) | SIFT deleterious (0); PolyPhen benign (0.043); catalogued as rs905784096, COSV60288205, COSV60305428; called by muse, mutect2, varscan2
- MUC2 | c.2298G>A p.M766I | Missense Mutation (SNP) | VAF 251/364 reads (69%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs1306307795; called by muse, mutect2, varscan2
- MUC4 | c.5834C>T p.A1945V | Missense Mutation (SNP) | VAF 160/677 reads (24%) | SIFT tolerated, low confidence (1); PolyPhen possibly damaging (0.494); catalogued as rs1356960383; called by muse, mutect2, varscan2
- MUC6 | c.3092G>A p.W1031* | Nonsense Mutation (SNP) | VAF 504/742 reads (68%) | catalogued as rs1230272516, COSV70135719; called by muse, mutect2, varscan2
- MYH2 | c.4990G>A p.D1664N | Missense Mutation (SNP) | VAF 128/376 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.925); catalogued as rs1451301582; called by muse, mutect2, varscan2
- MYH2 | c.4759G>A p.E1587K | Missense Mutation (SNP) | VAF 124/398 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.731); catalogued as COSV55448636, COSV99820366; called by muse, mutect2, varscan2
- MYH7B | c.1630G>A p.E544K | Missense Mutation (SNP) | VAF 111/450 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs749229876; called by muse, mutect2, varscan2
- MYH8 | c.4879G>A p.E1627K | Missense Mutation (SNP) | VAF 160/475 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); catalogued as COSV67962467; called by muse, mutect2, varscan2
- MYL4 | c.106G>A p.E36K | Missense Mutation (SNP) | VAF 175/529 reads (33%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.023); catalogued as rs1250854796; called by muse, mutect2, varscan2
- MYO3A | c.4592G>A p.G1531E | Missense Mutation (SNP) | VAF 53/169 reads (31%) | SIFT tolerated, low confidence (1); PolyPhen possibly damaging (0.734); catalogued as rs868284788; called by muse, mutect2, varscan2
- MYO7B | c.1523C>T p.S508F | Missense Mutation (SNP) | VAF 106/351 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV67351097; called by muse, mutect2, varscan2
- NEK4 | c.1600C>T p.R534* | Nonsense Mutation (SNP) | VAF 136/460 reads (30%) | catalogued as rs201029132; called by muse, mutect2, varscan2
- NEU2 | c.248G>A p.R83Q | Missense Mutation (SNP) | VAF 145/487 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.611); catalogued as rs144970536; called by muse, mutect2, varscan2
- NKX2-1 | c.523G>A p.E175K | Missense Mutation (SNP) | VAF 179/523 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as CM052003, COSV99072316; called by muse, mutect2, varscan2
- NLRP8 | c.1843G>A p.E615K | Missense Mutation (SNP) | VAF 89/297 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52585318; called by muse, mutect2, varscan2
- NOP53 | c.10G>A p.G4R | Missense Mutation (SNP) | VAF 104/307 reads (34%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.145); catalogued as rs1223467869; called by muse, mutect2, varscan2
- NOTCH4 | c.718C>T p.P240S | Missense Mutation (SNP) | VAF 254/846 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.024); catalogued as rs1046104152, COSV66682770; called by muse, mutect2
- NRAP | c.3820G>A p.E1274K (on ENST00000359988 / NM_001322945.2; = p.E1239K on NM_006175.4) | Missense Mutation (SNP) | VAF 73/234 reads (31%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.999); catalogued as rs1235091635; called by muse, mutect2, varscan2
- NRP1 | c.1679G>A p.R560Q | Missense Mutation (SNP) | VAF 154/454 reads (34%) | SIFT tolerated (0.86); PolyPhen possibly damaging (0.873); catalogued as rs773172539; called by muse, varscan2
- NTF3 | c.322G>A p.D108N | Missense Mutation (SNP) | VAF 352/686 reads (51%) | SIFT deleterious (0.02); PolyPhen benign (0.144); catalogued as rs371028635; called by muse, mutect2, varscan2
- NXF3 | c.1380G>A p.V460= | Splice Region (SNP) | VAF 135/210 reads (64%) | catalogued as COSV67704679; called by muse, mutect2, varscan2
- OAS3 | c.1165C>T p.P389S | Missense Mutation (SNP) | VAF 204/566 reads (36%) | SIFT tolerated (0.2); PolyPhen benign (0.185); catalogued as rs546772919, COSV57444454; called by muse, mutect2, varscan2
- OAS3 | c.3163G>A p.D1055N | Missense Mutation (SNP) | VAF 179/526 reads (34%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.946); catalogued as rs1159166072; called by muse, mutect2, varscan2
- OLFM3 | c.568G>A p.E190K (on ENST00000338858 / NM_001288821.1; = p.E170K on NM_058170.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 117/367 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.956); catalogued as COSV100129334, COSV58806239; called by muse, mutect2, varscan2
- OPN1LW | c.304G>A p.E102K | Missense Mutation (SNP) | VAF 221/347 reads (64%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.999); catalogued as COSV64065033; called by muse, mutect2, varscan2
- OR10C1 | c.632C>T p.P211L (on ENST00000622521; = p.P209L on NM_013941.3) | Missense Mutation (SNP) | VAF 257/765 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as COSV65822555; called by muse, mutect2, varscan2
- OR11H12 | c.691G>A p.G231R | Missense Mutation (SNP) | VAF 56/950 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.303); catalogued as rs1440534478; called by muse, mutect2
- OR11H2 | c.658G>A p.G220R (on ENST00000556246; = p.G231R on NM_001197287.1) | Missense Mutation (SNP) | VAF 75/782 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.25); catalogued as rs1388354307; called by muse, varscan2
- OR14K1 | c.644C>T p.S215F | Missense Mutation (SNP) | VAF 88/422 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs764245420, COSV99315001; called by muse, mutect2, varscan2
- OR1A1 | c.7G>A p.E3K | Missense Mutation (SNP) | VAF 64/213 reads (30%) | SIFT tolerated (0.92); PolyPhen benign (0.007); catalogued as rs1350313742, COSV58404407; called by muse, mutect2, varscan2
- OR1N2 | c.595G>A p.E199K | Missense Mutation (SNP) | VAF 139/372 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.018); catalogued as COSV65460257; called by muse, mutect2, varscan2
- OR2AP1 | c.80C>T p.T27I | Missense Mutation (SNP) | VAF 126/360 reads (35%) | SIFT tolerated, low confidence (0.97); PolyPhen benign (0); catalogued as rs1186915333; called by muse, mutect2, varscan2
- OR2B3 | c.728C>T p.S243F | Missense Mutation (SNP) | VAF 231/658 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65850766; called by muse, mutect2, varscan2
- OR2B6 | c.544C>T p.P182S | Missense Mutation (SNP) | VAF 138/325 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs762926555; called by muse, mutect2, varscan2
- OR2L2 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 35/197 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.216); catalogued as COSV63552066; called by muse, mutect2, varscan2
- OR2M7 | c.494C>T p.S165F | Missense Mutation (SNP) | VAF 227/513 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.33); catalogued as COSV58738071; called by muse, mutect2, varscan2
- OR4K17 | c.894G>A p.M298I | Missense Mutation (SNP) | VAF 45/170 reads (26%) | SIFT tolerated (0.15); PolyPhen benign (0.011); catalogued as COSV59647441; called by muse, varscan2
- OR4Q3 | c.146G>A p.G49E | Missense Mutation (SNP) | VAF 91/629 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.127); catalogued as COSV59177523; called by muse, mutect2, varscan2
- OR51E1 | c.533C>T p.S178F | Missense Mutation (SNP) | VAF 136/407 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV67810904; called by muse, mutect2, varscan2
- OR56A5 | c.700G>A p.E234K | Missense Mutation (SNP) | VAF 152/395 reads (38%) | SIFT tolerated (0.85); PolyPhen benign (0.01); catalogued as rs769313199; called by muse, mutect2, varscan2
- OR7D4 | c.46G>C p.G16R | Missense Mutation (SNP) | VAF 120/335 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as COSV100432775; called by muse, mutect2, varscan2
- OSBPL7 | c.2410C>T p.R804C | Missense Mutation (SNP) | VAF 106/307 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs754244117; called by muse, mutect2, varscan2
- OTOG | c.7432C>T p.P2478S | Missense Mutation (SNP) | VAF 350/538 reads (65%) | SIFT tolerated (0.82); PolyPhen benign (0.069); catalogued as COSV61129831; called by muse, mutect2, varscan2
- OTOP1 | c.867G>A p.W289* | Nonsense Mutation (SNP) | VAF 170/461 reads (37%) | catalogued as COSV56392599; called by muse, mutect2, varscan2
- P2RX6 | c.1093G>A p.E365K | Missense Mutation (SNP) | VAF 128/705 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.022); catalogued as rs142039298; called by muse, mutect2, varscan2
- PABPN1 | c.242dup p.A83Sfs*26 | Frame Shift Ins (INS) | VAF 218/593 reads (37%) | catalogued as rs767616144; called by mutect2, varscan2
- PAH | c.985G>T p.V329L | Missense Mutation (SNP) | VAF 101/310 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.501); catalogued as COSV61018795; called by muse, mutect2, varscan2
- PAPPA2 | c.169C>T p.R57* | Nonsense Mutation (SNP) | VAF 158/654 reads (24%) | catalogued as rs557625059, COSV100867139, COSV62772170; called by muse, varscan2
- PAPPA2 | c.280C>G p.R94G | Missense Mutation (SNP) | VAF 144/602 reads (24%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0); catalogued as COSV62776310; called by muse, varscan2
- PCDH15 | c.5324C>T p.S1775F | Missense Mutation (SNP) | VAF 152/443 reads (34%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as COSV57369057; called by muse, mutect2, varscan2
- PCDHA10 | c.455C>T p.P152L | Missense Mutation (SNP) | VAF 137/367 reads (37%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.043); catalogued as COSV56514351; called by muse, mutect2, varscan2
- PCDHA11 | c.629T>C p.L210S | Missense Mutation (SNP) | VAF 73/228 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as rs782783003; called by muse, mutect2, varscan2
- PCDHB1 | c.128C>T p.S43L | Missense Mutation (SNP) | VAF 169/555 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.876); catalogued as rs900032895; called by muse, mutect2, varscan2
- PDCL2 | c.381G>T p.L127F | Missense Mutation (SNP) | VAF 83/255 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV55262274; called by muse, mutect2, varscan2
- PDE10A | c.443G>A p.R148H | Missense Mutation (SNP) | VAF 118/399 reads (30%) | SIFT deleterious (0.05); PolyPhen benign (0.149); catalogued as rs1403420962, COSV63091276; called by muse, mutect2, varscan2
- PDE9A | c.841G>A p.D281N | Missense Mutation (SNP) | VAF 116/360 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.2); catalogued as rs773556425; called by muse, mutect2, varscan2
- PHEX | c.1399G>A p.E467K | Missense Mutation (SNP) | VAF 80/138 reads (58%) | SIFT deleterious (0); PolyPhen benign (0.038); catalogued as CM056035; called by muse, mutect2, varscan2
- PIK3C2G | c.1705C>T p.P569S | Missense Mutation (SNP) | VAF 145/351 reads (41%) | SIFT tolerated (0.58); PolyPhen probably damaging (0.998); catalogued as COSV56832306; called by muse, mutect2, varscan2
- PKHD1L1 | c.2235G>A p.Q745= | Splice Region (SNP) | VAF 56/161 reads (35%) | catalogued as rs1478584665; called by muse, mutect2, varscan2
- PKHD1L1 | c.8581G>A p.D2861N | Missense Mutation (SNP) | VAF 95/269 reads (35%) | SIFT tolerated (0.15); PolyPhen benign (0.417); catalogued as COSV65743428; called by muse, mutect2, varscan2
- PKP2 | c.1880C>T p.S627F | Missense Mutation (SNP) | VAF 125/406 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.442); catalogued as rs769817013, COSV50727422; called by muse, mutect2, varscan2
- PLA2G6 | c.869C>T p.P290L | Missense Mutation (SNP) | VAF 86/437 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs369017644; called by muse, mutect2, varscan2
- PLB1 | c.265G>A p.D89N | Missense Mutation (SNP) | VAF 149/449 reads (33%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as rs139585910; called by muse, mutect2, varscan2
- POTEC | c.1381C>T p.P461S | Missense Mutation (SNP) | VAF 55/149 reads (37%) | SIFT tolerated (0.14); PolyPhen benign (0.006); catalogued as COSV100742916; called by muse, mutect2, varscan2
- PPP1R3A | c.3193G>A p.E1065K | Missense Mutation (SNP) | VAF 143/1124 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.207); catalogued as rs368610339, COSV52880676; called by muse, mutect2, varscan2
- PRAMEF17 | c.1015C>T p.P339S | Missense Mutation (SNP) | VAF 86/211 reads (41%) | SIFT tolerated (0.14); PolyPhen benign (0.406); catalogued as rs1301185962; called by muse, mutect2, varscan2
- PREX2 | c.1231C>T p.L411F | Missense Mutation (SNP) | VAF 56/187 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.151); catalogued as COSV55759553; called by muse, mutect2, varscan2
- PRKAA2 | c.262G>A p.D88N | Missense Mutation (SNP) | VAF 67/246 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.985); catalogued as rs758607652, COSV64802171; called by muse, mutect2, varscan2
- PRR35 | c.595C>T p.P199S | Missense Mutation (SNP) | VAF 197/530 reads (37%) | SIFT tolerated (0.2); PolyPhen benign (0.031); catalogued as COSV99552320; called by muse, mutect2, varscan2
- PSD2 | c.1720C>T p.R574C | Missense Mutation (SNP) | VAF 149/475 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as rs150692464; called by muse, mutect2, varscan2
- PSG8 | c.1210G>A p.E404K | Missense Mutation (SNP) | VAF 141/766 reads (18%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.517); catalogued as COSV60612087; called by muse, mutect2, varscan2
- PTPRK | c.2419G>A p.D807N (on ENST00000368215 / NM_001291984.2; = p.D808N on NM_002844.4) | Missense Mutation (SNP) | VAF 156/516 reads (30%) | SIFT tolerated (0.05); PolyPhen benign (0.321); catalogued as COSV63908941; called by muse, mutect2, varscan2
- PTPRN2 | c.1180C>T p.R394C | Missense Mutation (SNP) | VAF 81/615 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.446); catalogued as rs772824315, COSV101235017, COSV67048198; called by muse, mutect2, varscan2
- PTPRO | c.2423C>T p.A808V | Missense Mutation (SNP) | VAF 89/326 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.026); catalogued as COSV55523392; called by muse, mutect2, varscan2
- PZP | c.3988C>T p.L1330F | Missense Mutation (SNP) | VAF 71/276 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.917); catalogued as COSV54369328; called by muse, mutect2, varscan2
- RAD54B | c.2179C>T p.L727F | Missense Mutation (SNP) | VAF 110/364 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs747079772; called by muse, mutect2, varscan2
- RASSF6 | c.409G>A p.D137N (on ENST00000342081 / NM_201431.2; = p.D105N on NM_177532.5) | Missense Mutation (SNP) | VAF 76/253 reads (30%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.737); catalogued as rs143969358, COSV56716501; called by muse, mutect2, varscan2
- REG1B | c.476C>T p.S159F | Missense Mutation (SNP) | VAF 116/329 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs866138170, COSV59308060; called by muse, mutect2
- REPIN1 | c.979C>T p.P327S | Missense Mutation (SNP) | VAF 187/1352 reads (14%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as rs1392048400; called by muse, mutect2, varscan2
- RGSL1 | c.1790A>G p.D597G | Missense Mutation (SNP) | VAF 115/418 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1558303485; called by muse, mutect2, varscan2
- RIPOR2 | c.2314C>T p.L772F | Missense Mutation (SNP) | VAF 148/447 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.868); catalogued as COSV104389167; called by muse, mutect2, varscan2
- RNF217 | c.1604G>A p.R535Q | Missense Mutation (SNP) | VAF 89/310 reads (29%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.987); catalogued as rs376223558; called by muse, mutect2, varscan2
- RP1L1 | c.5723C>T p.A1908V | Missense Mutation (SNP) | VAF 181/368 reads (49%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.16); catalogued as rs1030805223; called by muse, mutect2, varscan2
- SAGE1 | c.2506C>T p.R836* | Nonsense Mutation (SNP) | VAF 57/77 reads (74%) | catalogued as rs782625354, COSV61012285; called by muse, mutect2, varscan2
- SAMHD1 | c.367C>T p.H123Y | Missense Mutation (SNP) | VAF 116/411 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53429717; called by muse, mutect2, varscan2
- SCN11A | c.4478C>T p.S1493L | Missense Mutation (SNP) | VAF 110/383 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs374311646; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SEMA3A | c.1202C>T p.T401I | Missense Mutation (SNP) | VAF 574/826 reads (69%) | SIFT deleterious (0.03); PolyPhen benign (0.286); catalogued as rs771418664; called by muse, varscan2
- SEMA3D | c.151G>A p.D51N | Missense Mutation (SNP) | VAF 231/620 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.327); catalogued as rs1052847746; called by muse, mutect2, varscan2
- SERPINA10 | c.984G>A p.M328I | Missense Mutation (SNP) | VAF 88/318 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.754); catalogued as COSV56227462; called by muse, mutect2, varscan2
- SERPINA6 | c.412G>A p.E138K | Missense Mutation (SNP) | VAF 162/488 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as COSV58584126; called by muse, mutect2, varscan2
- SERPINB11 | c.95C>T p.S32L | Missense Mutation (SNP) | VAF 142/355 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.053); catalogued as rs375026731; called by muse, mutect2, varscan2
- SERPINB7 | c.313G>A p.E105K | Missense Mutation (SNP) | VAF 63/195 reads (32%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.967); catalogued as COSV60532713; called by muse, mutect2, varscan2
- SHISA3 | c.250G>A p.E84K | Missense Mutation (SNP) | VAF 109/355 reads (31%) | SIFT tolerated (0.21); PolyPhen benign (0.147); catalogued as COSV59979380; called by muse, mutect2, varscan2
- SKIDA1 | c.1642G>A p.D548N | Missense Mutation (SNP) | VAF 15/362 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.642); catalogued as rs1461016128; called by muse, mutect2
- SLC16A8 | c.1424A>G p.N475S | Missense Mutation (SNP) | VAF 207/876 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs569433346; called by muse, mutect2, varscan2
- SLC22A2 | c.448G>A p.D150N | Missense Mutation (SNP) | VAF 117/384 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.967); catalogued as rs762587387, COSV100870897; called by muse, mutect2, varscan2
- SLC22A3 | c.1208G>A p.R403H | Missense Mutation (SNP) | VAF 132/425 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as rs200478210, COSV51709707; called by muse, mutect2, varscan2
- SLC26A1 | c.163C>T p.P55S | Missense Mutation (SNP) | VAF 222/657 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56104460; called by muse, mutect2, varscan2
- SLC26A9 | c.673G>A p.G225R | Missense Mutation (SNP) | VAF 123/491 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs760280746, COSV61603490; called by muse, mutect2, varscan2
- SLC28A2 | c.171G>A p.R57= | Splice Region (SNP) | VAF 79/208 reads (38%) | catalogued as COSV100754628; called by muse, mutect2, varscan2
- SLC38A3 | c.1037-1G>A p.X346_splice | Splice Site (SNP) | VAF 100/322 reads (31%) | catalogued as COSV68844070; called by muse, mutect2, varscan2
- SLC38A4 | c.242C>T p.S81L | Missense Mutation (SNP) | VAF 138/398 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.139); catalogued as rs867582173; called by muse, mutect2, varscan2
- SLC39A2 | c.755G>A p.G252E | Missense Mutation (SNP) | VAF 181/597 reads (30%) | SIFT tolerated (0.24); PolyPhen benign (0.012); catalogued as COSV53869061; called by muse, mutect2, varscan2
- SLC44A5 | c.412G>A p.D138N | Missense Mutation (SNP) | VAF 89/283 reads (31%) | SIFT tolerated (0.93); PolyPhen benign (0); catalogued as rs1418118300; called by muse, mutect2, varscan2
- SLC45A3 | c.541A>G p.I181V | Missense Mutation (SNP) | VAF 461/880 reads (52%) | SIFT tolerated (0.54); PolyPhen benign (0.003); catalogued as rs1260943621; called by muse, mutect2, varscan2
- SLC6A15 | c.1369C>T p.P457S | Missense Mutation (SNP) | VAF 171/494 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV57024096; called by muse, mutect2, varscan2
- SMG7 | c.1693C>T p.P565S | Missense Mutation (SNP) | VAF 243/532 reads (46%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.015); catalogued as COSV61632261; called by muse, mutect2, varscan2
- SOBP | c.551G>A p.R184Q | Missense Mutation (SNP) | VAF 125/366 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV58002801; called by muse, mutect2, varscan2
- SOGA3 | c.500G>A p.G167E | Missense Mutation (SNP) | VAF 160/444 reads (36%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.007); catalogued as rs973981809; called by muse, mutect2, varscan2
- SORCS2 | c.2834C>T p.S945L | Missense Mutation (SNP) | VAF 157/439 reads (36%) | SIFT tolerated (0.12); PolyPhen benign (0.108); catalogued as rs1005466427, COSV100212652; called by muse, mutect2, varscan2
- SORL1 | c.5728C>T p.R1910C | Missense Mutation (SNP) | VAF 57/138 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs762818674; called by muse, mutect2, varscan2
- SPACA1 | c.436C>T p.R146C | Missense Mutation (SNP) | VAF 100/291 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs368572755, COSV52761709; called by muse, mutect2, varscan2
- SPAG17 | c.5836G>A p.E1946K | Missense Mutation (SNP) | VAF 85/249 reads (34%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs377326727; called by muse, mutect2, varscan2
- SPANXN2 | c.298G>A p.E100K | Missense Mutation (SNP) | VAF 234/390 reads (60%) | SIFT tolerated (0.07); PolyPhen benign (0.299); catalogued as rs201039433, COSV65129217; called by muse, mutect2, varscan2
- SPATS2 | c.1329A>G p.V443= | Splice Region (SNP) | VAF 98/287 reads (34%) | catalogued as rs751722158; called by muse, mutect2, varscan2
- SPEG | c.8714C>T p.S2905F | Missense Mutation (SNP) | VAF 140/412 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.735); catalogued as rs1394564669; called by muse, mutect2, varscan2
- SPHKAP | c.2464G>A p.D822N | Missense Mutation (SNP) | VAF 115/373 reads (31%) | SIFT tolerated (0.95); PolyPhen benign (0); catalogued as rs775866234, COSV60871291, COSV60892119; called by muse, mutect2, varscan2
- SSU72P3 | c.505G>A p.E169K | Missense Mutation (SNP) | VAF 94/1040 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.372); catalogued as rs894852036; called by muse, mutect2
- STAT3 | c.106C>T p.P36S | Missense Mutation (SNP) | VAF 94/302 reads (31%) | SIFT tolerated (0.84); PolyPhen probably damaging (0.995); catalogued as rs1292306960; called by muse, mutect2, varscan2
- STON1-GTF2A1L | c.2962C>T p.H988Y | Missense Mutation (SNP) | VAF 140/404 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.068); catalogued as COSV59135682; called by muse, mutect2, varscan2
- SULT1A2 | c.49G>A p.G17R | Missense Mutation (SNP) | VAF 185/552 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1202561751; called by muse, mutect2, varscan2
- SVEP1 | c.8929C>T p.P2977S | Missense Mutation (SNP) | VAF 135/436 reads (31%) | SIFT tolerated (0.18); PolyPhen benign (0.026); catalogued as COSV52842592; called by muse, mutect2, varscan2
- SYNE1 | c.22175G>A p.R7392K (on ENST00000367255 / NM_182961.4; = p.R7321K on NM_033071.3) | Missense Mutation (SNP) | VAF 95/269 reads (35%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.615); catalogued as rs1355964423, COSV55030171; called by muse, mutect2, varscan2
- SYNE1 | c.3466G>A p.D1156N (on ENST00000367255 / NM_182961.4; = p.D1163N on NM_033071.3) | Missense Mutation (SNP) | VAF 113/340 reads (33%) | SIFT tolerated (0.22); PolyPhen benign (0.007); catalogued as rs1207544980; called by muse, mutect2, varscan2
- SYT10 | c.1466G>A p.R489Q | Missense Mutation (SNP) | VAF 74/333 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.415); catalogued as rs755675734, COSV57339421; called by muse, mutect2, varscan2
- TASOR | c.3829C>T p.P1277S (on ENST00000355628 / NM_001365636.2; = p.P901S on NM_015224.3) | Missense Mutation (SNP) | VAF 71/172 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.92); catalogued as rs756833582, COSV62928339; called by muse, mutect2, varscan2
- TBX2 | c.535G>A p.D179N | Missense Mutation (SNP) | VAF 212/575 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.375); catalogued as COSV53598068; called by muse, mutect2, varscan2
- TDRD5 | c.2848C>T p.R950* | Nonsense Mutation (SNP) | VAF 216/403 reads (54%) | catalogued as rs1389771257, COSV104399707; called by muse, varscan2
- TINAG | c.388G>A p.G130R | Missense Mutation (SNP) | VAF 98/303 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.875); catalogued as rs748704001; called by muse, mutect2, varscan2
- TMC5 | c.2068G>A p.E690K (on ENST00000396229 / NM_001105248.1; = p.E444K on NM_024780.5) | Missense Mutation (SNP) | VAF 112/314 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs201778492, COSV54900449; called by muse, mutect2, varscan2
- TMPPE | c.161C>A p.S54* | Nonsense Mutation (SNP) | VAF 177/509 reads (35%) | catalogued as COSV56566867, COSV56567950; called by muse, mutect2, varscan2
- TNR | c.1711G>A p.E571K | Missense Mutation (SNP) | VAF 110/500 reads (22%) | SIFT tolerated (0.17); PolyPhen benign (0.334); catalogued as rs376305450; called by muse, mutect2, varscan2
- TOGARAM2 | c.1405G>A p.E469K | Missense Mutation (SNP) | VAF 115/382 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.257); catalogued as COSV65423840; called by muse, mutect2, varscan2
- TPSD1 | c.186G>A p.W62* | Nonsense Mutation (SNP) | VAF 229/731 reads (31%) | catalogued as COSV99273883; called by muse, mutect2, varscan2
- TRAV20 | c.226G>A p.E76K | Missense Mutation (SNP) | VAF 100/326 reads (31%) | SIFT tolerated (0.47); PolyPhen benign (0.012); catalogued as rs1453037638; called by muse, mutect2, varscan2
- TRIM58 | c.1060G>A p.E354K | Missense Mutation (SNP) | VAF 160/616 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as COSV63570618; called by muse, mutect2, varscan2
- TRIM77 | c.910G>A p.E304K | Missense Mutation (SNP) | VAF 141/269 reads (52%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs532293788, COSV68067452; called by muse, mutect2, varscan2
- TRIML1 | c.763G>A p.E255K | Missense Mutation (SNP) | VAF 92/404 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.097); catalogued as rs267600120; called by muse, mutect2, varscan2
- TRIOBP | c.3691C>T p.R1231C | Missense Mutation (SNP) | VAF 177/796 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.981); catalogued as rs751171100, COSV60382206; called by mutect2, varscan2
- TRMT9B | c.737C>T p.S246L | Missense Mutation (SNP) | VAF 114/231 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as rs760934307, COSV71600450; called by muse, mutect2, varscan2
- TTN | c.18071C>T p.S6024L (on ENST00000591111; = p.S5097L on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 174/492 reads (35%) | PolyPhen benign (0.306); catalogued as rs868170582, COSV59965477, COSV60280617; called by muse, mutect2, varscan2
- UGT1A7 | c.563C>T p.S188F | Missense Mutation (SNP) | VAF 145/449 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60830276; called by muse, mutect2, varscan2
- USF1 | c.850G>A p.D284N | Missense Mutation (SNP) | VAF 175/361 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.131); catalogued as COSV99230849; called by muse, mutect2, varscan2
- VPS13A | c.5506C>T p.H1836Y | Missense Mutation (SNP) | VAF 90/311 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs770055324; called by muse, mutect2, varscan2
- VPS13A | c.6691G>A p.G2231R | Missense Mutation (SNP) | VAF 134/442 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs574905172, COSV62429255; called by muse, mutect2, varscan2
- WASHC2C | c.3410C>T p.S1137F (on ENST00000336378; = p.S1116F on NM_015262.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 200/628 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); catalogued as rs1462524493; called by muse, mutect2, varscan2
- XIRP1 | c.884C>T p.S295F | Missense Mutation (SNP) | VAF 195/548 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs866783562, COSV61138913; called by muse, mutect2, varscan2
- ZFHX2 | c.5123G>A p.G1708E | Missense Mutation (SNP) | VAF 153/475 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1384243559; called by muse, mutect2, varscan2
- ZFHX4 | c.1744G>A p.E582K | Missense Mutation (SNP) | VAF 154/476 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.113); catalogued as rs1333886732, COSV51488119; called by muse, mutect2, varscan2
- ZFYVE26 | c.5899A>G p.N1967D | Missense Mutation (SNP) | VAF 180/489 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); catalogued as rs1167012323; called by muse, mutect2, varscan2
- ZMYM1 | c.3274C>T p.R1092C | Missense Mutation (SNP) | VAF 91/296 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as rs778059950, COSV63251983; called by muse, mutect2, varscan2
- ZNF222 | c.1003C>T p.H335Y | Missense Mutation (SNP) | VAF 102/311 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV51826269; called by muse, mutect2, varscan2
- ZNF425 | c.550C>T p.P184S | Missense Mutation (SNP) | VAF 791/1059 reads (75%) | SIFT tolerated (0.62); PolyPhen benign (0.312); catalogued as COSV65200754; called by muse, mutect2, varscan2
- ZNF676 | c.1402C>T p.L468F (on ENST00000650058; = p.L436F on NM_001001411.3) | Missense Mutation (SNP) | VAF 136/426 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs1291089740, COSV68092354; called by mutect2, varscan2
- ZNF695 | c.700C>T p.H234Y | Missense Mutation (SNP) | VAF 120/523 reads (23%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.675); catalogued as rs1395327620, COSV100377385; called by muse, mutect2, varscan2
- ZNF735 | c.313G>A p.D105N | Missense Mutation (SNP) | VAF 225/634 reads (35%) | SIFT tolerated (0.11); PolyPhen benign (0.197); catalogued as COSV70035752; called by muse, mutect2, varscan2
- ZNF786 | c.520C>T p.P174S | Missense Mutation (SNP) | VAF 973/1313 reads (74%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.693); catalogued as COSV100302866; called by muse, mutect2, varscan2
- ZNF804A | c.1361C>T p.S454F | Missense Mutation (SNP) | VAF 83/273 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs866013097, COSV56433687; called by muse, mutect2, varscan2
- A2M | c.2386C>T p.L796F | Missense Mutation (SNP) | VAF 92/944 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.835); called by muse, mutect2
- AADACL2 | c.26G>A p.G9E | Missense Mutation (SNP) | VAF 103/345 reads (30%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.567); called by muse, mutect2, varscan2
- ABCA13 | c.14556A>T p.K4852N | Missense Mutation (SNP) | VAF 297/802 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.119); called by muse, mutect2, varscan2
- ABCA4 | c.2771G>A p.G924E | Missense Mutation (SNP) | VAF 116/353 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- ABCB11 | c.968G>A p.G323E | Missense Mutation (SNP) | VAF 143/420 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ACSM1 | c.749G>A p.G250E | Missense Mutation (SNP) | VAF 84/251 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- ACVR1C | c.1091G>A p.G364E | Missense Mutation (SNP) | VAF 71/216 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ADAM19 | c.451C>T p.P151S | Missense Mutation (SNP) | VAF 110/329 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADAM7 | c.1688G>A p.G563E | Missense Mutation (SNP) | VAF 111/318 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- ADAMTS13 | c.2230C>T p.P744S | Missense Mutation (SNP) | VAF 105/323 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.743); called by muse, mutect2, varscan2
- ADAMTS8 | c.1408G>A p.D470N | Missense Mutation (SNP) | VAF 186/391 reads (48%) | SIFT tolerated (0.08); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ADCY10 | c.1552C>T p.P518S | Missense Mutation (SNP) | VAF 93/514 reads (18%) | SIFT tolerated (0.45); PolyPhen benign (0); called by muse, mutect2, varscan2
- ADGB | c.3653G>A p.R1218K | Missense Mutation (SNP) | VAF 120/419 reads (29%) | SIFT tolerated (0.16); PolyPhen benign (0.258); called by muse, mutect2, varscan2
- ADGRD2 | c.1141G>A p.G381R | Missense Mutation (SNP) | VAF 119/357 reads (33%) | SIFT tolerated (0.21); PolyPhen benign (0.16); called by muse, mutect2, varscan2
- AHSP | c.85G>A p.D29N | Missense Mutation (SNP) | VAF 76/207 reads (37%) | SIFT tolerated (0.34); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- AK9 | c.1544C>T p.T515I | Missense Mutation (SNP) | VAF 118/314 reads (38%) | SIFT tolerated (0.19); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- AMELX | c.514C>T p.P172S | Missense Mutation (SNP) | VAF 169/256 reads (66%) | SIFT deleterious (0.03); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- APOF | c.185C>T p.P62L | Missense Mutation (SNP) | VAF 176/490 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.294); called by muse, mutect2, varscan2
- ARFGEF1 | c.785A>T p.E262V | Missense Mutation (SNP) | VAF 158/498 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0); called by muse, mutect2, varscan2
- ARHGEF35 | c.863G>A p.G288E | Missense Mutation (SNP) | VAF 58/1699 reads (3%) | SIFT tolerated (0.22); PolyPhen benign (0.029); called by muse, mutect2
- ATAD2B | c.1889C>T p.P630L | Missense Mutation (SNP) | VAF 131/378 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ATP12A | c.800-8C>T | Splice Region (SNP) | VAF 72/284 reads (25%) | called by muse, mutect2
- ATP13A3 | c.3260T>A p.V1087E | Missense Mutation (SNP) | VAF 93/305 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); called by muse, mutect2, varscan2
- ATP4B | c.112G>A p.V38M | Missense Mutation (SNP) | VAF 109/343 reads (32%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ATP9A | c.3116C>T p.P1039L | Missense Mutation (SNP) | VAF 123/514 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- BCAM | c.1772G>A p.G591E | Missense Mutation (SNP) | VAF 152/438 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.272); called by muse, mutect2, varscan2
- BOD1L1 | c.4595C>T p.P1532L | Missense Mutation (SNP) | VAF 107/359 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- C16orf96 | c.1456G>A p.D486N | Missense Mutation (SNP) | VAF 247/673 reads (37%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.549); called by muse, varscan2
- C1R | c.1363G>A p.G455R (on ENST00000536053 / NM_001354346.2; = p.G441R on NM_001733.7) | Missense Mutation (SNP) | VAF 106/535 reads (20%) | SIFT tolerated (0.66); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- CACNA1E | c.5884G>A p.E1962K | Missense Mutation (SNP) | VAF 104/452 reads (23%) | SIFT tolerated (0.18); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- CACNA1H | c.5768G>A p.R1923K | Missense Mutation (SNP) | VAF 184/544 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.675); called by muse, mutect2, varscan2
- CACNA2D4 | c.2626G>A p.D876N | Missense Mutation (SNP) | VAF 192/995 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.223); called by muse, mutect2, varscan2
- CACNB2 | c.265G>A p.E89K (on ENST00000324631 / NM_201596.3; = p.E34K on NM_000724.4) | Missense Mutation (SNP) | VAF 123/398 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- CAP1 | c.505C>T p.L169F | Missense Mutation (SNP) | VAF 67/234 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.443); called by muse, mutect2, varscan2
- CC2D2B | c.1651G>A p.E551K | Missense Mutation (SNP) | VAF 70/190 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.47); called by muse, mutect2, varscan2
- CCDC27 | c.979G>A p.E327K | Missense Mutation (SNP) | VAF 52/313 reads (17%) | SIFT tolerated (0.32); PolyPhen benign (0.262); called by muse, mutect2, varscan2
- CCDC88C | c.1609G>A p.E537K | Missense Mutation (SNP) | VAF 132/450 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- CD99L2 | c.146C>T p.T49I | Missense Mutation (SNP) | VAF 172/247 reads (70%) | SIFT tolerated (0.42); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CEP290 | c.1177C>T p.Q393* | Nonsense Mutation (SNP) | VAF 33/107 reads (31%) | called by muse, mutect2, varscan2
- CFAP46 | c.5534G>A p.G1845E | Missense Mutation (SNP) | VAF 156/521 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- CFAP47 | c.5290C>T p.R1764* | Nonsense Mutation (SNP) | VAF 80/116 reads (69%) | called by muse, mutect2, varscan2
- CFAP54 | c.1393C>T p.P465S | Missense Mutation (SNP) | VAF 95/307 reads (31%) | SIFT tolerated (0.43); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- CFAP54 | c.5116G>A p.G1706R | Missense Mutation (SNP) | VAF 71/203 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- CHAT | c.1849G>A p.G617R | Missense Mutation (SNP) | VAF 107/325 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CHRNA9 | c.1237G>A p.E413K | Missense Mutation (SNP) | VAF 161/461 reads (35%) | SIFT tolerated (0.36); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CIITA | c.1574T>G p.L525R | Missense Mutation (SNP) | VAF 145/454 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); called by muse, varscan2
- COBL | c.2428G>A p.D810N | Missense Mutation (SNP) | VAF 414/1070 reads (39%) | SIFT tolerated (0.26); PolyPhen benign (0.15); called by muse, mutect2, varscan2
- COL22A1 | c.4117G>T p.E1373* | Nonsense Mutation (SNP) | VAF 124/399 reads (31%) | called by muse, mutect2, varscan2
- COL3A1 | c.3146C>T p.P1049L | Missense Mutation (SNP) | VAF 117/394 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, varscan2
- COL4A3 | c.1585G>A p.G529S | Missense Mutation (SNP) | VAF 72/235 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COL5A2 | c.887C>T p.P296L | Missense Mutation (SNP) | VAF 107/333 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- COL6A3 | c.5095A>T p.K1699* | Nonsense Mutation (SNP) | VAF 131/406 reads (32%) | called by muse, mutect2, varscan2
- CPNE6 | c.1276G>A p.E426K | Missense Mutation (SNP) | VAF 149/418 reads (36%) | SIFT tolerated (0.37); PolyPhen benign (0.117); called by muse, mutect2, varscan2
- CPNE7 | c.1256C>T p.S419F | Missense Mutation (SNP) | VAF 140/262 reads (53%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.908); called by muse, mutect2, varscan2
- CREB5 | c.446C>T p.S149F (on ENST00000357727 / NM_182898.4; = p.S142F on NM_004904.3) | Missense Mutation (SNP) | VAF 307/558 reads (55%) | SIFT deleterious (0.01); PolyPhen benign (0.328); called by muse, mutect2, varscan2
- CROCC | c.4066G>A p.E1356K | Missense Mutation (SNP) | VAF 118/333 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.198); called by muse, mutect2, varscan2
- CRYL1 | c.794C>T p.T265I | Missense Mutation (SNP) | VAF 90/301 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.86); called by muse, varscan2
- CRYL1 | c.793A>C p.T265P | Missense Mutation (SNP) | VAF 90/299 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.846); called by muse, varscan2
- CSMD3 | c.683G>A p.W228* | Nonsense Mutation (SNP) | VAF 107/326 reads (33%) | called by muse, mutect2, varscan2
- CSNK1G2 | c.948C>G p.F316L | Missense Mutation (SNP) | VAF 200/557 reads (36%) | SIFT tolerated (0.46); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- CTAGE15 | c.1444G>A p.E482K | Missense Mutation (SNP) | VAF 43/994 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.919); called by muse, mutect2
- CUZD1 | c.1205C>T p.S402F | Missense Mutation (SNP) | VAF 91/331 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CXCL5 | c.209C>T p.A70V | Missense Mutation (SNP) | VAF 125/372 reads (34%) | SIFT tolerated (0.14); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- CYP19A1 | c.206G>A p.G69E | Missense Mutation (SNP) | VAF 144/490 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CYP2S1 | c.1108G>A p.G370R | Missense Mutation (SNP) | VAF 149/451 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CYP3A7 | c.1096T>A p.L366I | Missense Mutation (SNP) | VAF 109/1126 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.41); called by muse, mutect2
- DCC | c.229G>A p.D77N | Missense Mutation (SNP) | VAF 144/429 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- DCDC1 | c.4106T>G p.V1369G (on ENST00000597505 / NM_001367979.1; = p.V476G on NM_020869.3) | Missense Mutation (SNP) | VAF 86/260 reads (33%) | SIFT deleterious (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- DIRAS2 | c.481C>T p.L161F | Missense Mutation (SNP) | VAF 124/362 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- DMGDH | c.595A>G p.T199A | Missense Mutation (SNP) | VAF 119/333 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.499); called by muse, mutect2, varscan2
- DNAH17 | c.12158C>T p.P4053L | Missense Mutation (SNP) | VAF 134/379 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.816); called by muse, mutect2, varscan2
- DNAH7 | c.4841G>A p.G1614E | Missense Mutation (SNP) | VAF 117/351 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DNAL4 | c.239A>T p.E80V | Missense Mutation (SNP) | VAF 171/885 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- DNAL4 | c.238G>T p.E80* | Nonsense Mutation (SNP) | VAF 170/883 reads (19%) | called by muse, mutect2, varscan2
- DNMBP | c.4067C>T p.S1356F | Missense Mutation (SNP) | VAF 125/366 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DOCK3 | c.1186C>T p.P396S | Missense Mutation (SNP) | VAF 105/304 reads (35%) | SIFT tolerated (0.35); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- DPP6 | c.361G>A p.E121K (on ENST00000377770 / NM_001364500.2; = p.E59K on NM_001936.5) | Missense Mutation (SNP) | VAF 278/415 reads (67%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- DPP8 | c.710G>A p.W237* (on ENST00000341861 / NM_001320875.2; = p.W221* on NM_017743.6) | Nonsense Mutation (SNP) | VAF 99/319 reads (31%) | called by muse, mutect2, varscan2
- DRAM1 | c.472C>T p.H158Y | Missense Mutation (SNP) | VAF 158/401 reads (39%) | SIFT tolerated (1); PolyPhen possibly damaging (0.56); called by muse, mutect2, varscan2
- ECPAS | c.2853C>G p.H951Q | Missense Mutation (SNP) | VAF 144/469 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.704); called by muse, mutect2, varscan2
- EGFLAM | c.1546C>T p.P516S | Missense Mutation (SNP) | VAF 160/414 reads (39%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- EMB | c.13C>T p.P5S | Missense Mutation (SNP) | VAF 51/326 reads (16%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- EML5 | c.1247A>T p.Y416F | Missense Mutation (SNP) | VAF 100/312 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ENAM | c.3025G>A p.E1009K | Missense Mutation (SNP) | VAF 144/418 reads (34%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- ENTPD8 | c.19G>A p.E7K | Missense Mutation (SNP) | VAF 128/407 reads (31%) | SIFT tolerated (0.82); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- EPAS1 | c.410C>T p.P137L | Missense Mutation (SNP) | VAF 95/327 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ERC2 | c.1641G>A p.K547= | Splice Region (SNP) | VAF 83/223 reads (37%) | called by muse, mutect2, varscan2
- ERVV-1 | c.601C>T p.P201S | Missense Mutation (SNP) | VAF 151/559 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.641); called by muse, mutect2, varscan2
- EXOC5 | c.1364G>A p.C455Y | Missense Mutation (SNP) | VAF 111/287 reads (39%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- EXPH5 | c.4970G>A p.S1657N | Missense Mutation (SNP) | VAF 148/305 reads (49%) | SIFT tolerated (0.34); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- EZH2 | c.694C>T p.P232S | Missense Mutation (SNP) | VAF 282/866 reads (33%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- F13A1 | c.275C>T p.P92L | Missense Mutation (SNP) | VAF 132/367 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.364); called by muse, mutect2, varscan2
- FAM135B | c.3964C>T p.H1322Y | Missense Mutation (SNP) | VAF 117/376 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FAM171A2 | c.713C>T p.P238L | Missense Mutation (SNP) | VAF 162/455 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- FAM184B | c.616G>A p.E206K | Missense Mutation (SNP) | VAF 189/566 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- FAM214A | c.2248G>A p.E750K | Missense Mutation (SNP) | VAF 91/255 reads (36%) | SIFT tolerated (0.11); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- FAM3B | c.145G>A p.E49K | Missense Mutation (SNP) | VAF 102/329 reads (31%) | SIFT tolerated (0.95); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- FAM83B | c.1441A>T p.M481L | Missense Mutation (SNP) | VAF 99/335 reads (30%) | SIFT tolerated (0.24); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- FOXK1 | c.670C>T p.P224S | Missense Mutation (SNP) | VAF 573/790 reads (73%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- FPR2 | c.316G>A p.D106N | Missense Mutation (SNP) | VAF 159/444 reads (36%) | SIFT tolerated (0.17); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- GAD2 | c.345G>A p.M115I | Missense Mutation (SNP) | VAF 115/357 reads (32%) | SIFT tolerated (0.17); PolyPhen benign (0); called by muse, mutect2, varscan2
- GAS2L2 | c.178G>A p.E60K | Missense Mutation (SNP) | VAF 169/526 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- GBP1 | c.920G>A p.G307E | Missense Mutation (SNP) | VAF 129/398 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- GFPT2 | c.1171G>A p.E391K | Missense Mutation (SNP) | VAF 90/302 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- GKN2 | c.43G>A p.G15R | Missense Mutation (SNP) | VAF 140/436 reads (32%) | SIFT tolerated (0.14); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- GNE | c.1283C>T p.S428F (on ENST00000396594 / NM_001128227.3; = p.S397F on NM_005476.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 139/265 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- GPR89A | c.868G>A p.G290S | Missense Mutation (SNP) | VAF 22/178 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by mutect2, varscan2
- GPR89B | c.868G>A p.G290S | Missense Mutation (SNP) | VAF 41/177 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- GRAMD2B | c.1235C>G p.A412G | Missense Mutation (SNP) | VAF 84/281 reads (30%) | SIFT tolerated (0.14); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- GRHL2 | c.382C>T p.Q128* | Nonsense Mutation (SNP) | VAF 191/490 reads (39%) | called by muse, mutect2, varscan2
- GRIN2B | c.3599A>G p.N1200S | Missense Mutation (SNP) | VAF 154/653 reads (24%) | SIFT tolerated (0.22); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- GSAP | c.1892A>G p.E631G | Missense Mutation (SNP) | VAF 114/841 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- GSTM2 | c.570A>T p.E190D | Missense Mutation (SNP) | VAF 79/253 reads (31%) | SIFT tolerated (0.17); PolyPhen benign (0.277); called by muse, mutect2, varscan2
- HACE1 | c.2516C>T p.S839F | Missense Mutation (SNP) | VAF 62/247 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- HECW1 | c.750G>C p.E250D | Missense Mutation (SNP) | VAF 271/691 reads (39%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- HIVEP3 | c.6830A>T p.E2277V | Missense Mutation (SNP) | VAF 193/532 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.368); called by muse, mutect2, varscan2
- IBTK | c.1667A>G p.E556G | Missense Mutation (SNP) | VAF 115/306 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- IGHV1-58 | c.292G>A p.A98T | Missense Mutation (SNP) | VAF 80/272 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.361); called by muse, mutect2, varscan2
- IGLV5-45 | c.85C>T p.L29F | Missense Mutation (SNP) | VAF 142/681 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.196); called by muse, mutect2, varscan2
- IRAG2 | c.707T>C p.F236S | Missense Mutation (SNP) | VAF 142/327 reads (43%) | SIFT tolerated, low confidence (0.33); called by muse, mutect2
- IRAG2 | c.1648G>A p.G550R | Missense Mutation (SNP) | VAF 60/279 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- ITGA5 | c.2731T>G p.C911G | Missense Mutation (SNP) | VAF 100/287 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- ITGA7 | c.346A>C p.K116Q | Missense Mutation (SNP) | VAF 129/355 reads (36%) | SIFT tolerated (0.24); PolyPhen benign (0.052); called by muse, mutect2, varscan2
- JAKMIP1 | c.1640G>A p.G547E | Missense Mutation (SNP) | VAF 78/278 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KCNQ5 | c.1166C>T p.S389F | Missense Mutation (SNP) | VAF 116/378 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.36); called by muse, mutect2, varscan2
- KIAA1109 | c.13867C>T p.H4623Y | Missense Mutation (SNP) | VAF 99/327 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- KIAA1522 | c.841C>T p.P281S (on ENST00000373480 / NM_001198972.2; = p.P340S on NM_020888.3) | Missense Mutation (SNP) | VAF 52/397 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- KIF26A | c.3028G>A p.E1010K | Missense Mutation (SNP) | VAF 164/556 reads (29%) | SIFT tolerated (0.34); PolyPhen benign (0.156); called by muse, varscan2
- KLHL6 | c.720G>A p.M240I | Missense Mutation (SNP) | VAF 146/407 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- KRT82 | c.260G>A p.G87E | Missense Mutation (SNP) | VAF 182/562 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- KRTAP12-3 | c.184C>T p.P62S | Missense Mutation (SNP) | VAF 202/566 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- LCA5 | c.790G>A p.A264T | Missense Mutation (SNP) | VAF 121/334 reads (36%) | SIFT tolerated (0.36); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- LCT | c.4375G>A p.D1459N | Missense Mutation (SNP) | VAF 132/407 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.216); called by muse, mutect2, varscan2
- LMOD2 | c.382G>A p.E128K | Missense Mutation (SNP) | VAF 769/1019 reads (75%) | SIFT tolerated (0.07); PolyPhen benign (0.077); called by muse, varscan2
- LMOD2 | c.1084G>A p.E362K | Missense Mutation (SNP) | VAF 863/1183 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- LPIN3 | c.910G>A p.G304S | Missense Mutation (SNP) | VAF 168/665 reads (25%) | SIFT tolerated (0.87); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- LRGUK | c.1164C>G p.H388Q | Missense Mutation (SNP) | VAF 352/939 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LRP1B | c.817G>A p.E273K | Missense Mutation (SNP) | VAF 62/216 reads (29%) | SIFT tolerated (0.19); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- LRP2 | c.10376C>T p.P3459L | Missense Mutation (SNP) | VAF 145/373 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- LRRC37B | c.781C>T p.H261Y | Missense Mutation (SNP) | VAF 133/427 reads (31%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.718); called by muse, mutect2, varscan2
- MALRD1 | c.406C>T p.L136F | Missense Mutation (SNP) | VAF 92/306 reads (30%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- MALRD1 | c.1913C>T p.S638F | Missense Mutation (SNP) | VAF 73/262 reads (28%) | SIFT tolerated (0.25); PolyPhen benign (0.119); called by muse, mutect2, varscan2
- MARCHF6 | c.2435C>T p.P812L | Missense Mutation (SNP) | VAF 190/536 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MCTP2 | c.2211G>A p.E737= | Splice Region (SNP) | VAF 79/272 reads (29%) | called by muse, mutect2, varscan2
- MED12L | c.4125T>A p.N1375K | Missense Mutation (SNP) | VAF 153/444 reads (34%) | SIFT tolerated (0.31); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- MEFV | c.535A>G p.S179G | Missense Mutation (SNP) | VAF 27/710 reads (4%) | SIFT tolerated (0.26); PolyPhen benign (0.001); called by muse, mutect2
- MEP1B | c.1667G>A p.G556D | Missense Mutation (SNP) | VAF 157/481 reads (33%) | SIFT tolerated (0.46); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- MLIP | c.488C>T p.S163F | Missense Mutation (SNP) | VAF 165/545 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- MMP13 | c.209A>G p.E70G | Missense Mutation (SNP) | VAF 159/269 reads (59%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- MPP7 | c.374C>T p.P125L | Missense Mutation (SNP) | VAF 56/191 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MUC16 | c.31855C>T p.H10619Y | Missense Mutation (SNP) | VAF 98/320 reads (31%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.019); called by mutect2, varscan2
- MUC16 | c.12167G>A p.R4056K | Missense Mutation (SNP) | VAF 112/321 reads (35%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- MUC2 | c.2299G>A p.D767N | Missense Mutation (SNP) | VAF 235/343 reads (69%) | SIFT tolerated (0.2); PolyPhen benign (0.018); called by muse, varscan2
- MYBPC2 | c.1742G>A p.G581E | Missense Mutation (SNP) | VAF 105/313 reads (34%) | SIFT tolerated (0.14); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- MYO15A | c.2788G>A p.D930N | Missense Mutation (SNP) | VAF 148/475 reads (31%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.57); called by muse, mutect2, varscan2
- MYRFL | c.1844G>A p.G615E | Missense Mutation (SNP) | VAF 81/295 reads (27%) | SIFT tolerated (0.86); PolyPhen benign (0.168); called by muse, mutect2, varscan2
- NARF | c.614T>G p.V205G | Missense Mutation (SNP) | VAF 85/271 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- NCOA5 | c.1165C>A p.Q389K | Missense Mutation (SNP) | VAF 114/516 reads (22%) | SIFT tolerated (0.65); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- NECTIN2 | c.388_393dup p.L130_T131dup | In Frame Ins (INS) | VAF 146/480 reads (30%) | called by mutect2, varscan2
- NF1 | c.293C>T p.P98L | Missense Mutation (SNP) | VAF 53/160 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.209); called by muse, mutect2, varscan2
- NOL11 | c.2044A>C p.I682L | Missense Mutation (SNP) | VAF 82/194 reads (42%) | SIFT tolerated (0.09); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- NPAS4 | c.2213G>A p.G738E | Missense Mutation (SNP) | VAF 133/283 reads (47%) | SIFT tolerated (0.54); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- NPHS1 | c.3436A>T p.S1146C | Missense Mutation (SNP) | VAF 156/484 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.635); called by muse, mutect2, varscan2
- NPHS2 | c.649C>T p.L217F | Missense Mutation (SNP) | VAF 142/600 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- NRP1 | c.1553G>A p.G518E | Missense Mutation (SNP) | VAF 146/430 reads (34%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.944); called by muse, varscan2
- NUP98 | c.1919C>T p.P640L | Missense Mutation (SNP) | VAF 80/271 reads (30%) | SIFT tolerated (0.22); PolyPhen benign (0); called by muse, mutect2, varscan2
- OBSCN | c.20668G>A p.G6890R | Missense Mutation (SNP) | VAF 507/986 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- OBSL1 | c.1198C>T p.H400Y | Missense Mutation (SNP) | VAF 216/643 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- OBSL1 | c.946C>T p.L316F | Missense Mutation (SNP) | VAF 184/548 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OGDHL | c.2389C>T p.P797S | Missense Mutation (SNP) | VAF 101/307 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- OR4E1 | c.277G>A p.E93K | Missense Mutation (SNP) | VAF 135/391 reads (35%) | SIFT tolerated (0.74); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- OR4N5 | c.713C>T p.S238F | Missense Mutation (SNP) | VAF 117/347 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OR9H1P | c.433G>A p.G145R | Missense Mutation (SNP) | VAF 112/446 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, varscan2
- OTOL1 | c.545G>A p.G182E | Missense Mutation (SNP) | VAF 114/317 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- P4HA1 | c.383T>C p.V128A | Missense Mutation (SNP) | VAF 115/373 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PAK5 | c.1367G>A p.G456E | Missense Mutation (SNP) | VAF 357/670 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PAK5 | c.302G>A p.R101K | Missense Mutation (SNP) | VAF 322/617 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- PAK6 | c.1814C>T p.S605F | Missense Mutation (SNP) | VAF 152/474 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- PARP15 | c.438A>T p.E146D | Missense Mutation (SNP) | VAF 137/364 reads (38%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.547); called by muse, mutect2, varscan2
- PCBP2 | c.644C>T p.S215F | Missense Mutation (SNP) | VAF 163/492 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- PCDH15 | c.4457C>A p.S1486Y | Missense Mutation (SNP) | VAF 133/402 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.515); called by muse, mutect2, varscan2
- PCDHGA7 | c.1759C>A p.L587M | Missense Mutation (SNP) | VAF 173/514 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PCDHGB6 | c.79C>T p.P27S | Missense Mutation (SNP) | VAF 141/425 reads (33%) | SIFT tolerated (0.71); PolyPhen benign (0.147); called by muse, mutect2, varscan2
- PCLO | c.2024C>T p.S675L | Missense Mutation (SNP) | VAF 446/1184 reads (38%) | SIFT tolerated (0.16); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- PCNT | c.6532C>T p.P2178S | Missense Mutation (SNP) | VAF 152/439 reads (35%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.815); called by muse, mutect2, varscan2
- PDCD1 | c.107C>T p.T36I | Missense Mutation (SNP) | VAF 150/518 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); called by muse, mutect2, varscan2
- PEX6 | c.1912C>T p.L638F | Missense Mutation (SNP) | VAF 142/436 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PGS1 | c.1075C>T p.P359S | Missense Mutation (SNP) | VAF 143/365 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PHACTR3 | c.872G>A p.S291N | Missense Mutation (SNP) | VAF 199/875 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- PI4KA | c.1167G>A p.K389= | Splice Region (SNP) | VAF 112/514 reads (22%) | called by muse, mutect2, varscan2
- PIK3R5 | c.2363C>T p.S788F | Missense Mutation (SNP) | VAF 128/351 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- PKHD1 | c.4738C>T p.P1580S | Missense Mutation (SNP) | VAF 108/340 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PKHD1L1 | c.10784G>A p.G3595E | Missense Mutation (SNP) | VAF 132/388 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- PLA2R1 | c.2345C>G p.T782R | Missense Mutation (SNP) | VAF 116/390 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.691); called by muse, mutect2, varscan2
- PLEKHA3 | c.364C>T p.L122F | Missense Mutation (SNP) | VAF 160/430 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.677); called by muse, mutect2, varscan2
- PLSCR4 | c.266C>T p.P89L | Missense Mutation (SNP) | VAF 138/430 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- PLXDC1 | c.439C>T p.P147S | Missense Mutation (SNP) | VAF 132/359 reads (37%) | SIFT tolerated (0.4); PolyPhen benign (0.15); called by muse, mutect2, varscan2
- PMPCA | c.905G>A p.R302K | Missense Mutation (SNP) | VAF 87/260 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PPP2R3A | c.2881T>A p.F961I | Missense Mutation (SNP) | VAF 92/301 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- PRDM1 | c.838C>T p.L280F | Missense Mutation (SNP) | VAF 169/521 reads (32%) | SIFT tolerated (0.52); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- PRKAR2B | c.502G>A p.D168N | Missense Mutation (SNP) | VAF 70/671 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.665); called by muse, mutect2, varscan2
- PRKCD | c.47C>T p.S16F | Missense Mutation (SNP) | VAF 113/324 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PRMT8 | c.982C>T p.P328S | Missense Mutation (SNP) | VAF 223/435 reads (51%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- PRPF19 | c.229G>A p.A77T | Missense Mutation (SNP) | VAF 13/240 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2
- PSME4 | c.544C>T p.P182S | Missense Mutation (SNP) | VAF 116/284 reads (41%) | SIFT tolerated (0.51); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- PTGS2 | c.796C>T p.P266S | Missense Mutation (SNP) | VAF 124/555 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.389); called by muse, varscan2
- PTPRQ | c.2677G>A p.E893K (on ENST00000616559; = p.E851K on NM_001145026.2) | Missense Mutation (SNP) | VAF 66/189 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PZP | c.2404C>T p.L802F | Missense Mutation (SNP) | VAF 219/472 reads (46%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.903); called by muse, mutect2, varscan2
- QSOX1 | c.1343G>A p.G448D | Missense Mutation (SNP) | VAF 403/737 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- RBM15B | c.356C>T p.P119L | Missense Mutation (SNP) | VAF 144/459 reads (31%) | SIFT tolerated (0.3); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RBPJL | c.1213C>T p.H405Y | Missense Mutation (SNP) | VAF 233/518 reads (45%) | SIFT tolerated (0.81); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- RDH16 | c.544G>A p.G182S | Missense Mutation (SNP) | VAF 97/377 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- REM1 | c.457G>A p.G153R | Missense Mutation (SNP) | VAF 247/455 reads (54%) | SIFT deleterious (0.01); PolyPhen benign (0.118); called by muse, mutect2, varscan2
- RERGL | c.613G>T p.V205F | Missense Mutation (SNP) | VAF 57/261 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- RIMS1 | c.4617G>A p.M1539I | Missense Mutation (SNP) | VAF 96/243 reads (40%) | SIFT tolerated (0.15); PolyPhen benign (0.355); called by muse, mutect2, varscan2
- RIMS2 | c.4069G>A p.G1357R (on ENST00000666250 / NM_001348490.2; = p.G928R on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 92/286 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); called by muse, mutect2, varscan2
- RNASE4 | c.70C>T p.Q24* | Nonsense Mutation (SNP) | VAF 169/453 reads (37%) | called by muse, mutect2, varscan2
- RNF17 | c.1648G>A p.D550N | Missense Mutation (SNP) | VAF 115/346 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.172); called by muse, mutect2, varscan2
- RORB | c.596C>T p.S199F (on ENST00000396204 / NM_001365023.1; = p.S188F on NM_006914.4) | Missense Mutation (SNP) | VAF 124/448 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- RP1L1 | c.1232C>T p.P411L | Missense Mutation (SNP) | VAF 138/270 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- RPE65 | c.250A>T p.I84F | Missense Mutation (SNP) | VAF 81/240 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.213); called by muse, mutect2, varscan2
- RTBDN | c.632C>T p.T211I (on ENST00000393233 / NM_001270444.1; = p.T243I on NM_031429.2) | Missense Mutation (SNP) | VAF 122/386 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- RYR1 | c.2480A>G p.E827G | Missense Mutation (SNP) | VAF 173/476 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.926); called by muse, mutect2, varscan2
- SCN3A | c.2075C>T p.S692L | Missense Mutation (SNP) | VAF 108/316 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.511); called by muse, varscan2
- SCN3A | c.1381G>A p.A461T | Missense Mutation (SNP) | VAF 93/242 reads (38%) | SIFT deleterious (0.05); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- SETBP1 | c.3449G>A p.R1150K | Missense Mutation (SNP) | VAF 148/434 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- SETDB2 | c.2156T>C p.L719S | Missense Mutation (SNP) | VAF 126/182 reads (69%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); called by muse, mutect2, varscan2
- SEZ6L2 | c.34C>T p.P12S | Missense Mutation (SNP) | VAF 159/462 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SFRP4 | c.336G>A p.M112I | Missense Mutation (SNP) | VAF 282/740 reads (38%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.771); called by muse, mutect2, varscan2
- SHANK1 | c.2843C>T p.S948F | Missense Mutation (SNP) | VAF 203/554 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.236); called by muse, mutect2, varscan2
- SIPA1L1 | c.3019C>T p.H1007Y | Missense Mutation (SNP) | VAF 148/431 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- SIPA1L3 | c.79C>T p.P27S | Missense Mutation (SNP) | VAF 170/513 reads (33%) | SIFT tolerated (0.18); PolyPhen benign (0.005); called by muse, varscan2
- SLC17A1 | c.1079C>T p.S360F | Missense Mutation (SNP) | VAF 127/432 reads (29%) | SIFT tolerated (0.33); PolyPhen benign (0.097); called by muse, mutect2, varscan2
- SLC25A17 | c.511C>T p.P171S | Missense Mutation (SNP) | VAF 169/829 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.734); called by muse, mutect2, varscan2
- SLC26A9 | c.674G>A p.G225E | Missense Mutation (SNP) | VAF 120/489 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC29A4 | c.871G>A p.D291N | Missense Mutation (SNP) | VAF 108/448 reads (24%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.601); called by muse, mutect2, varscan2
- SLC2A10 | c.323T>C p.V108A | Missense Mutation (SNP) | VAF 388/758 reads (51%) | SIFT tolerated (0.29); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- SLC39A12 | c.1098_1100del p.K366_Y367delinsN | In Frame Del (DEL) | VAF 101/284 reads (36%) | called by mutect2, pindel, varscan2
- SLC43A2 | c.707G>A p.G236E | Missense Mutation (SNP) | VAF 112/375 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.292); called by muse, mutect2, varscan2
- SLC5A5 | c.1490C>T p.A497V | Missense Mutation (SNP) | VAF 144/418 reads (34%) | SIFT tolerated (0.35); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SLC8A1 | c.2111C>A p.P704H | Missense Mutation (SNP) | VAF 134/409 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLFN11 | c.2101T>G p.F701V | Missense Mutation (SNP) | VAF 129/419 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLTM | c.2284T>A p.S762T | Missense Mutation (SNP) | VAF 182/502 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.708); called by muse, mutect2, varscan2
- SMARCD2 | c.91C>T p.P31S | Missense Mutation (SNP) | VAF 148/474 reads (31%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SMC4 | c.3571C>T p.L1191F | Missense Mutation (SNP) | VAF 91/289 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SPDYE3 | c.593G>A p.R198K | Missense Mutation (SNP) | VAF 634/1060 reads (60%) | SIFT tolerated (0.11); called by muse, mutect2, varscan2
- SPEN | c.2545G>A p.E849K | Missense Mutation (SNP) | VAF 151/533 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.411); called by muse, mutect2, varscan2
- SPG11 | c.292C>T p.P98S | Missense Mutation (SNP) | VAF 119/371 reads (32%) | SIFT tolerated (0.53); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- SPTA1 | c.901G>A p.G301R | Missense Mutation (SNP) | VAF 83/492 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.356); called by muse, mutect2, varscan2
- SPTLC3 | c.1025G>A p.G342E | Missense Mutation (SNP) | VAF 133/498 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SRRM4 | c.1280G>A p.R427K | Missense Mutation (SNP) | VAF 81/252 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.98); called by muse, varscan2
- SSU72P4 | c.505G>A p.E169K | Missense Mutation (SNP) | VAF 141/1484 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.556); called by muse, mutect2
- STIMATE | c.575T>A p.L192* | Nonsense Mutation (SNP) | VAF 124/394 reads (31%) | called by muse, mutect2, varscan2
- STYXL2 | c.2989A>G p.N997D | Missense Mutation (SNP) | VAF 95/470 reads (20%) | SIFT tolerated (0.66); PolyPhen benign (0); called by muse, mutect2, varscan2
- TAS2R41 | c.581C>T p.S194F | Missense Mutation (SNP) | VAF 601/840 reads (72%) | SIFT tolerated (0.44); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- TENM3 | c.4174C>T p.P1392S | Missense Mutation (SNP) | VAF 147/713 reads (21%) | SIFT tolerated (0.55); PolyPhen benign (0); called by muse, mutect2, varscan2
- TENT5C | c.122T>A p.F41Y | Missense Mutation (SNP) | VAF 101/327 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.274); called by muse, mutect2, varscan2
- TEX101 | c.102G>A p.M34I (on ENST00000598265 / NM_001130011.3; = p.M52I on NM_031451.4) | Missense Mutation (SNP) | VAF 135/412 reads (33%) | SIFT tolerated (0.39); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TEX15 | c.7667C>T p.P2556L (on ENST00000256246; = p.P2939L on NM_001350162.2) | Missense Mutation (SNP) | VAF 101/314 reads (32%) | SIFT tolerated (0.22); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- TEX35 | c.622G>A p.G208S | Missense Mutation (SNP) | VAF 117/505 reads (23%) | SIFT tolerated, low confidence (0.32); PolyPhen possibly damaging (0.72); called by muse, mutect2, varscan2
- TEX35 | c.623G>A p.G208D | Missense Mutation (SNP) | VAF 109/472 reads (23%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.795); called by muse, varscan2
- TH | c.1071G>A p.P357= (on ENST00000381178 / NM_199292.3; = p.P326= on NM_000360.4) | Splice Region (SNP) | VAF 323/447 reads (72%) | called by muse, mutect2, varscan2
- THBS1 | c.238G>A p.D80N | Missense Mutation (SNP) | VAF 207/588 reads (35%) | SIFT tolerated, low confidence (0.19); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- TLR4 | c.1981C>T p.L661F (on ENST00000355622 / NM_138554.5; = p.L621F on NM_003266.4) | Missense Mutation (SNP) | VAF 144/438 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- TLR7 | c.439C>T p.P147S | Missense Mutation (SNP) | VAF 208/306 reads (68%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TLR8 | c.1084A>C p.N362H (on ENST00000218032 / NM_138636.5; = p.N380H on NM_016610.4) | Missense Mutation (SNP) | VAF 113/156 reads (72%) | SIFT tolerated (0.19); PolyPhen benign (0.141); called by muse, mutect2, varscan2
- TMEM108 | c.734C>T p.S245F | Missense Mutation (SNP) | VAF 144/463 reads (31%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TNFRSF19 | c.434A>G p.Y145C | Missense Mutation (SNP) | VAF 94/317 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TOE1 | c.865C>T p.P289S | Missense Mutation (SNP) | VAF 153/404 reads (38%) | SIFT tolerated (0.34); PolyPhen benign (0.381); called by muse, mutect2, varscan2
- TPD52L1 | c.95C>T p.S32F | Missense Mutation (SNP) | VAF 101/309 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TRAPPC10 | c.515C>T p.S172F | Missense Mutation (SNP) | VAF 98/324 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.223); called by muse, mutect2, varscan2
- TRAV17 | c.109G>A p.E37K | Missense Mutation (SNP) | VAF 121/306 reads (40%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.453); called by muse, mutect2, varscan2
- TRBV5-1 | c.8C>T p.S3F | Missense Mutation (SNP) | VAF 140/1132 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- TRIM64 | c.559A>T p.I187L | Missense Mutation (SNP) | VAF 58/143 reads (41%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- TRIOBP | c.4154G>A p.G1385E | Missense Mutation (SNP) | VAF 216/936 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- TRIP11 | c.5836C>T p.L1946F | Missense Mutation (SNP) | VAF 138/452 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TRPC4 | c.1771G>A p.E591K | Missense Mutation (SNP) | VAF 261/389 reads (67%) | SIFT tolerated (0.54); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- TRPM6 | c.1950T>A p.H650Q | Missense Mutation (SNP) | VAF 154/483 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TRUB1 | c.724T>A p.F242I | Missense Mutation (SNP) | VAF 103/319 reads (32%) | SIFT tolerated (0.23); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- TSHZ2 | c.1408G>A p.E470K | Missense Mutation (SNP) | VAF 95/483 reads (20%) | SIFT tolerated (0.36); PolyPhen benign (0.197); called by muse, mutect2, varscan2
- TTC33 | c.258G>A p.W86* | Nonsense Mutation (SNP) | VAF 114/326 reads (35%) | called by muse, mutect2, varscan2
- TTN | c.74603G>A p.G24868D (on ENST00000591111; = p.G17444D on NM_003319.4) | Missense Mutation (SNP) | VAF 126/437 reads (29%) | PolyPhen benign (0.073); called by muse, mutect2, varscan2
- TTN | c.66912G>A p.W22304* (on ENST00000591111; = p.W14880* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 156/469 reads (33%) | called by muse, mutect2, varscan2
- TTN | c.27760G>A p.D9254N (on ENST00000591111; = p.D8327N on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 116/329 reads (35%) | PolyPhen possibly damaging (0.544); called by muse, mutect2, varscan2
- UNC45B | c.207C>T p.A69= | Splice Region (SNP) | VAF 106/289 reads (37%) | called by muse, mutect2, varscan2
- USH2A | c.4450C>T p.H1484Y | Missense Mutation (SNP) | VAF 281/532 reads (53%) | SIFT tolerated (0.16); PolyPhen benign (0.099); called by muse, mutect2
- USP44 | c.1634G>A p.R545K | Missense Mutation (SNP) | VAF 74/249 reads (30%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- VCL | c.2057C>T p.P686L | Missense Mutation (SNP) | VAF 82/309 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- VIM | c.250G>A p.V84M | Missense Mutation (SNP) | VAF 154/489 reads (31%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.588); called by muse, mutect2, varscan2
- VPS13B | c.4235C>T p.T1412I | Missense Mutation (SNP) | VAF 142/419 reads (34%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- VWA7 | c.2404G>A p.V802M | Missense Mutation (SNP) | VAF 271/793 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- WDR97 | c.4576C>T p.P1526S | Missense Mutation (SNP) | VAF 146/403 reads (36%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.373); called by muse, mutect2, varscan2
- XDH | c.748G>A p.A250T | Missense Mutation (SNP) | VAF 152/475 reads (32%) | SIFT tolerated (0.3); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- ZBED2 | c.46G>A p.A16T | Missense Mutation (SNP) | VAF 134/438 reads (31%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.175); called by muse, mutect2, varscan2
- ZNF214 | c.863C>T p.S288F | Missense Mutation (SNP) | VAF 237/374 reads (63%) | SIFT tolerated (0.07); PolyPhen benign (0.003); called by muse, varscan2
- ZNF292 | c.4123T>A p.F1375I | Missense Mutation (SNP) | VAF 116/387 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.637); called by muse, mutect2, varscan2
- ZNF366 | c.733G>A p.D245N | Missense Mutation (SNP) | VAF 196/531 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.769); called by muse, mutect2, varscan2
- ZNF451 | c.562G>A p.G188R | Missense Mutation (SNP) | VAF 67/216 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF644 | c.3004G>A p.E1002K | Missense Mutation (SNP) | VAF 153/484 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- ZNF649 | c.1512T>A p.H504Q | Missense Mutation (SNP) | VAF 86/240 reads (36%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.127); called by muse, mutect2, varscan2
- ZNF665 | c.746G>A p.G249E (on ENST00000600412; = p.G314E on NM_024733.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 163/473 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF846 | c.466C>T p.P156S | Missense Mutation (SNP) | VAF 108/338 reads (32%) | SIFT tolerated (0.19); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- AADACL4 | c.520C>T p.L174= | Silent (SNP) | VAF 152/496 reads (31%) | called by muse, mutect2, varscan2
- ABCA8 | c.3063C>T p.S1021= | Silent (SNP) | VAF 124/398 reads (31%) | catalogued as rs761652738, COSV52210373; called by muse, mutect2, varscan2
- ABCG8 | c.1597C>T p.L533= | Silent (SNP) | VAF 196/584 reads (34%) | called by muse, varscan2
- ABHD16B | c.129G>A p.R43= | Silent (SNP) | VAF 212/786 reads (27%) | called by muse, mutect2, varscan2
- AC099489.1 | c.1116G>A p.T372= | Silent (SNP) | VAF 160/403 reads (40%) | catalogued as rs1022039091; called by muse, mutect2, varscan2
- ACAP3 | c.579C>T p.F193= | Silent (SNP) | VAF 179/473 reads (38%) | catalogued as rs769631697; called by muse, mutect2, varscan2
- ACD | c.153C>T p.L51= | Silent (SNP) | VAF 139/272 reads (51%) | catalogued as rs1207134820, COSV54665585, COSV54667112, COSV54669526; called by muse, mutect2, varscan2
- ACOT12 | c.1329G>A p.L443= | Silent (SNP) | VAF 102/313 reads (33%) | called by muse, mutect2, varscan2
- ACP2 | c.105C>T p.F35= | Silent (SNP) | VAF 115/224 reads (51%) | catalogued as COSV57044249; called by muse, mutect2, varscan2
- ACSM1 | c.414C>T p.F138= | Silent (SNP) | VAF 53/185 reads (29%) | called by muse, mutect2, varscan2
- ADAM19 | c.1965G>A p.G655= | Silent (SNP) | VAF 108/306 reads (35%) | called by muse, mutect2, varscan2
- ADAMTS16 | c.2583G>A p.G861= | Silent (SNP) | VAF 185/524 reads (35%) | catalogued as rs767753888, COSV57007066; called by muse, mutect2, varscan2
- ADCY8 | c.2163C>T p.I721= | Silent (SNP) | VAF 115/337 reads (34%) | catalogued as rs760033182, COSV53908206; called by muse, mutect2, varscan2
- ADGRE1 | c.1704G>A p.V568= | Silent (SNP) | VAF 123/440 reads (28%) | called by muse, mutect2, varscan2
- ADHFE1 | c.798C>T p.P266= | Silent (SNP) | VAF 136/478 reads (28%) | called by muse, mutect2, varscan2
- AFAP1 | c.1512C>A p.V504= | Silent (SNP) | VAF 112/367 reads (31%) | called by muse, mutect2, varscan2
- AK5 | c.303C>T p.I101= (on ENST00000354567 / NM_174858.3; = p.I75= on NM_012093.4) | Silent (SNP) | VAF 137/383 reads (36%) | called by muse, mutect2, varscan2
- ALG5 | c.675C>T p.F225= | Silent (SNP) | VAF 222/337 reads (66%) | catalogued as rs1407809977, COSV53507453; called by muse, mutect2, varscan2
- ALK | c.765C>T p.F255= | Silent (SNP) | VAF 106/282 reads (38%) | catalogued as rs771377569, COSV66595097; called by muse, mutect2, varscan2
- ANKMY1 | c.1077A>G p.P359= | Silent (SNP) | VAF 59/186 reads (32%) | catalogued as rs1347274707, COSV56042181; called by muse, mutect2, varscan2
- ANO4 | c.2109G>A p.P703= (on ENST00000392977 / NM_001286615.2; = p.P668= on NM_178826.4) | Silent (SNP) | VAF 130/384 reads (34%) | catalogued as rs372248204; called by muse, mutect2, varscan2
- ANTXRL | c.33C>T p.F11= | Silent (SNP) | VAF 112/312 reads (36%) | called by muse, varscan2
- AOC3 | c.1974G>A p.V658= | Silent (SNP) | VAF 125/367 reads (34%) | called by muse, mutect2, varscan2
- ARHGAP20 | c.864C>T p.F288= | Silent (SNP) | VAF 112/223 reads (50%) | called by muse, mutect2, varscan2
- ARL4D | c.78C>T p.V26= | Silent (SNP) | VAF 171/499 reads (34%) | called by muse, mutect2, varscan2
- ARMC4 | c.2916G>A p.L972= | Silent (SNP) | VAF 116/327 reads (35%) | catalogued as COSV59467764; called by muse, mutect2, varscan2
- ARNT | c.2040C>T p.S680= | Silent (SNP) | VAF 340/678 reads (50%) | called by muse, mutect2, varscan2
- AVEN | c.651G>A p.K217= | Silent (SNP) | VAF 119/395 reads (30%) | called by muse, mutect2, varscan2
- B3GAT2 | c.156C>T p.L52= | Silent (SNP) | VAF 167/520 reads (32%) | catalogued as rs1276792381; called by muse, mutect2, varscan2
- BMP3 | c.39C>T p.G13= | Silent (SNP) | VAF 85/284 reads (30%) | called by muse, mutect2, varscan2
- BNC1 | c.1554C>T p.I518= | Silent (SNP) | VAF 167/510 reads (33%) | called by muse, mutect2, varscan2
- BRPF1 | c.903C>T p.H301= | Silent (SNP) | VAF 142/397 reads (36%) | catalogued as COSV57403061; called by muse, mutect2, varscan2
- BRSK2 | c.1584G>A p.L528= | Silent (SNP) | VAF 187/281 reads (67%) | catalogued as rs1272260589; called by muse, mutect2, varscan2
- C12orf56 | c.420G>A p.K140= | Silent (SNP) | VAF 84/268 reads (31%) | called by muse, mutect2, varscan2
- C1R | c.1362G>A p.K454= (on ENST00000536053 / NM_001354346.2; = p.K440= on NM_001733.7) | Silent (SNP) | VAF 104/538 reads (19%) | called by muse, mutect2, varscan2
- C1orf141 | c.735C>T p.F245= | Silent (SNP) | VAF 64/230 reads (28%) | catalogued as rs267598698, COSV63992364; called by muse, mutect2, varscan2
- C2CD2 | c.1647C>T p.S549= | Silent (SNP) | VAF 181/514 reads (35%) | catalogued as rs368197262; called by muse, mutect2, varscan2
- C2orf16 | c.1239C>T p.I413= | Silent (SNP) | VAF 118/345 reads (34%) | called by muse, mutect2, varscan2
- CALB1 | c.12C>T p.S4= | Silent (SNP) | VAF 121/376 reads (32%) | catalogued as rs372729705; called by muse, mutect2, varscan2
- CAMTA1 | c.1182C>T p.S394= | Silent (SNP) | VAF 47/398 reads (12%) | called by muse, mutect2, varscan2
- CATSPERD | c.2079C>T p.I693= | Silent (SNP) | VAF 100/302 reads (33%) | catalogued as rs573139640, COSV58467063; called by muse, mutect2, varscan2
- CCDC68 | c.501G>A p.L167= | Silent (SNP) | VAF 59/214 reads (28%) | catalogued as COSV100491968, COSV61604896; called by muse, mutect2, varscan2
- CD300LD | c.144C>T p.Y48= | Silent (SNP) | VAF 116/341 reads (34%) | called by muse, mutect2, varscan2
- CD93 | c.1464G>A p.E488= | Silent (SNP) | VAF 183/682 reads (27%) | called by muse, mutect2, varscan2
- CDC42EP4 | c.825C>T p.S275= | Silent (SNP) | VAF 180/555 reads (32%) | called by muse, mutect2, varscan2
- CDCA7L | c.57C>T p.A19= | Silent (SNP) | VAF 102/579 reads (18%) | called by muse, mutect2, varscan2
- CDH4 | c.1074C>T p.I358= | Silent (SNP) | VAF 113/474 reads (24%) | catalogued as rs780170651, COSV64641324; called by muse, mutect2, varscan2
- CDHR2 | c.1074C>T p.L358= | Silent (SNP) | VAF 117/454 reads (26%) | catalogued as COSV56143215; called by muse, mutect2, varscan2
- CDK19 | c.1287C>T p.S429= | Silent (SNP) | VAF 208/569 reads (37%) | catalogued as rs1158529764; called by muse, mutect2, varscan2
- CDSN | c.21C>T p.P7= | Silent (SNP) | VAF 204/641 reads (32%) | called by muse, mutect2, varscan2
- CELSR3 | c.8793C>T p.A2931= | Silent (SNP) | VAF 172/482 reads (36%) | called by muse, mutect2, varscan2
- CEP170B | c.3204C>T p.T1068= (on ENST00000453495; = p.T997= on NM_015005.3) | Silent (SNP) | VAF 201/569 reads (35%) | called by muse, mutect2, varscan2
- CFH | c.3189G>A p.Q1063= | Silent (SNP) | VAF 112/810 reads (14%) | catalogued as COSV100809759; called by muse, mutect2
- CHD4 | c.5265G>A p.K1755= (on ENST00000357008 / NM_001363606.2; = p.K1766= on NM_001273.5) | Silent (SNP) | VAF 145/589 reads (25%) | called by muse, mutect2, varscan2
- CHL1 | c.1527G>A p.L509= (on ENST00000397491 / NM_001253387.1; = p.L525= on NM_006614.4) | Silent (SNP) | VAF 77/268 reads (29%) | called by muse, mutect2, varscan2
- CHRM3 | c.1572C>T p.T524= | Silent (SNP) | VAF 145/597 reads (24%) | catalogued as COSV55103344; called by muse, mutect2, varscan2
- CIITA | c.1632C>T p.L544= | Silent (SNP) | VAF 176/506 reads (35%) | called by muse, varscan2
- CLCA2 | c.2793G>A p.K931= | Silent (SNP) | VAF 65/226 reads (29%) | catalogued as COSV100991482; called by muse, mutect2, varscan2
- CMYA5 | c.8895C>T p.I2965= | Silent (SNP) | VAF 127/380 reads (33%) | catalogued as rs369437195; called by muse, mutect2, varscan2
- CNR2 | c.171G>A p.L57= | Silent (SNP) | VAF 168/482 reads (35%) | catalogued as rs759118298; called by muse, mutect2, varscan2
- CNTN2 | c.3000C>T p.I1000= | Silent (SNP) | VAF 91/375 reads (24%) | catalogued as rs947096199, COSV59348045; called by muse, mutect2, varscan2
- COL15A1 | c.2637G>A p.G879= | Silent (SNP) | VAF 124/388 reads (32%) | called by muse, mutect2, varscan2
- COL6A2 | c.459C>T p.T153= | Silent (SNP) | VAF 207/541 reads (38%) | catalogued as rs764014106; ClinVar: likely benign / conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- COX8C | c.51G>A p.L17= | Silent (SNP) | VAF 196/563 reads (35%) | catalogued as rs1199576932; called by muse, mutect2, varscan2
- CPNE9 | c.1446G>A p.R482= | Silent (SNP) | VAF 178/490 reads (36%) | called by muse, mutect2, varscan2
- CRYL1 | c.819C>T p.S273= | Silent (SNP) | VAF 178/257 reads (69%) | called by muse, varscan2
- CSMD2 | c.5730G>A p.P1910= | Silent (SNP) | VAF 82/281 reads (29%) | catalogued as rs370267917; called by muse, mutect2, varscan2
- CSMD3 | c.9825G>A p.G3275= (on ENST00000297405 / NM_001363185.1; = p.G3106= on NM_052900.3) | Silent (SNP) | VAF 116/359 reads (32%) | catalogued as rs1483398830; called by muse, mutect2, varscan2
- CSN1S1 | c.495C>T p.S165= | Silent (SNP) | VAF 111/391 reads (28%) | catalogued as rs1168866381, COSV55890159; called by muse, varscan2
- CSRNP1 | c.408G>A p.R136= | Silent (SNP) | VAF 120/401 reads (30%) | called by muse, mutect2, varscan2
- CXCR1 | c.783C>T p.V261= | Silent (SNP) | VAF 193/566 reads (34%) | called by muse, mutect2, varscan2
- CYP2C19 | c.1472G>A p.*491= | Silent (SNP) | VAF 68/202 reads (34%) | catalogued as COSV64909060; called by muse, mutect2, varscan2
- CYP2C9 | c.300C>T p.F100= | Silent (SNP) | VAF 124/359 reads (35%) | catalogued as rs267602639, COSV53253253; called by muse, mutect2, varscan2
- CYSLTR1 | c.711C>T p.V237= | Silent (SNP) | VAF 190/263 reads (72%) | catalogued as rs1269052746, COSV64821043; called by muse, mutect2, varscan2
- DDX19A | c.255C>T p.S85= | Silent (SNP) | VAF 139/275 reads (51%) | catalogued as COSV56359906; called by muse, mutect2, varscan2
- DHRS3 | c.525C>T p.S175= | Silent (SNP) | VAF 142/382 reads (37%) | catalogued as rs145040210; called by muse, mutect2, varscan2
- DKK4 | c.411G>A p.R137= | Silent (SNP) | VAF 104/317 reads (33%) | catalogued as COSV99612655; called by muse, mutect2, varscan2
- DNAH17 | c.12159C>T p.P4053= | Silent (SNP) | VAF 133/375 reads (35%) | called by muse, mutect2, varscan2
- DNAH3 | c.486G>A p.T162= | Silent (SNP) | VAF 113/348 reads (32%) | catalogued as rs1229606843, COSV99768866; called by muse, mutect2, varscan2
- DNAH6 | c.5154G>T p.V1718= | Silent (SNP) | VAF 80/270 reads (30%) | called by muse, mutect2, varscan2
- DNMT3B | c.360C>T p.S120= | Silent (SNP) | VAF 120/590 reads (20%) | catalogued as rs144034337; called by muse, varscan2
- DPF2 | c.972C>T p.C324= | Silent (SNP) | VAF 137/265 reads (52%) | called by muse, mutect2, varscan2
- DPP7 | c.925C>T p.L309= | Silent (SNP) | VAF 143/472 reads (30%) | called by muse, mutect2, varscan2
- DPP7 | c.864C>T p.P288= | Silent (SNP) | VAF 130/387 reads (34%) | catalogued as rs147788989; called by muse, mutect2, varscan2
- DST | c.17199C>T p.S5733= (on ENST00000361203 / NM_001374722.1; = p.S3430= on NM_015548.5) | Silent (SNP) | VAF 75/269 reads (28%) | catalogued as COSV55005298; called by muse, mutect2, varscan2
- ECH1 | c.408C>T p.A136= | Silent (SNP) | VAF 118/369 reads (32%) | called by muse, mutect2, varscan2
- ELL2 | c.1089C>T p.L363= | Silent (SNP) | VAF 143/406 reads (35%) | called by muse, mutect2
- ENPP6 | c.843G>A p.G281= | Silent (SNP) | VAF 119/430 reads (28%) | catalogued as COSV57066691; called by muse, mutect2, varscan2
- EPAS1 | c.411C>T p.P137= | Silent (SNP) | VAF 95/334 reads (28%) | called by muse, mutect2, varscan2
- EPPK1 | c.2169G>A p.Q723= | Silent (SNP) | VAF 293/887 reads (33%) | called by muse, mutect2, varscan2
- ERC1 | c.210C>T p.G70= | Silent (SNP) | VAF 404/580 reads (70%) | called by muse, varscan2
- ERICH3 | c.1230G>A p.P410= | Silent (SNP) | VAF 112/340 reads (33%) | catalogued as rs375773806; called by muse, varscan2
- ESYT3 | c.642G>A p.G214= | Silent (SNP) | VAF 133/345 reads (39%) | catalogued as rs987728046, COSV56680299; called by muse, mutect2, varscan2
- EVPL | c.5820G>A p.L1940= | Silent (SNP) | VAF 190/561 reads (34%) | called by muse, mutect2, varscan2
- FABP3 | c.141G>A p.G47= | Silent (SNP) | VAF 191/459 reads (42%) | catalogued as rs749130570; called by muse, mutect2, varscan2
- FAM171A1 | c.1641C>T p.H547= | Silent (SNP) | VAF 170/468 reads (36%) | called by muse, mutect2, varscan2
- FBXO24 | c.1494G>A p.G498= (on ENST00000241071 / NM_033506.3; = p.G536= on NM_012172.5) | Silent (SNP) | VAF 550/1431 reads (38%) | called by muse, mutect2, varscan2
- FHDC1 | c.1989C>T p.L663= | Silent (SNP) | VAF 177/509 reads (35%) | catalogued as rs1311402641; called by muse, mutect2, varscan2
- FKBP15 | c.2335T>C p.L779= | Silent (SNP) | VAF 141/413 reads (34%) | catalogued as rs777972376; called by muse, mutect2, varscan2
- FREM3 | c.3216C>T p.V1072= | Silent (SNP) | VAF 103/364 reads (28%) | called by muse, mutect2, varscan2
- FYB2 | c.1713C>T p.S571= | Silent (SNP) | VAF 97/288 reads (34%) | catalogued as rs1362371763; called by muse, mutect2, varscan2
- GABBR1 | c.1173C>T p.F391= | Silent (SNP) | VAF 199/575 reads (35%) | called by muse, mutect2, varscan2
- GALR1 | c.120C>T p.F40= | Silent (SNP) | VAF 178/518 reads (34%) | catalogued as rs764880864; called by muse, mutect2
- GDPD5 | c.468C>T p.S156= | Silent (SNP) | VAF 124/231 reads (54%) | catalogued as rs771632107, COSV61130224; called by muse, mutect2, varscan2
- GHR | c.1197C>T p.F399= | Silent (SNP) | VAF 137/453 reads (30%) | catalogued as COSV50109103; called by muse, mutect2, varscan2
- GIMAP6 | c.189G>A p.R63= | Silent (SNP) | VAF 158/1433 reads (11%) | catalogued as rs1328199100, COSV61033369; called by muse, mutect2, varscan2
- GPAM | c.1182T>G p.G394= | Silent (SNP) | VAF 76/253 reads (30%) | called by muse, mutect2, varscan2
- GPATCH8 | c.1530C>T p.S510= | Silent (SNP) | VAF 128/343 reads (37%) | called by muse, mutect2, varscan2
- GPR1 | c.120C>T p.V40= | Silent (SNP) | VAF 172/436 reads (39%) | catalogued as rs776202834; called by muse, mutect2, varscan2
- GPR135 | c.1209G>A p.E403= | Silent (SNP) | VAF 174/571 reads (30%) | called by muse, mutect2, varscan2
- GRIN2A | c.2325C>T p.I775= | Silent (SNP) | VAF 105/343 reads (31%) | catalogued as rs748291723; ClinVar: likely benign / benign; called by muse, mutect2, varscan2
- GRIN2B | c.189C>T p.S63= | Silent (SNP) | VAF 264/531 reads (50%) | catalogued as rs199707487, COSV74205268; ClinVar: likely benign / conflicting interpretations of pathogenicity / uncertain significance; called by muse, mutect2, varscan2
- GRM3 | c.681C>T p.I227= | Silent (SNP) | VAF 128/1066 reads (12%) | catalogued as COSV64469711; called by muse, mutect2, varscan2
- GSAP | c.429G>A p.K143= | Silent (SNP) | VAF 365/941 reads (39%) | called by muse, mutect2, varscan2
- GSDMC | c.447G>A p.R149= | Silent (SNP) | VAF 125/395 reads (32%) | catalogued as rs1392606667; called by muse, mutect2, varscan2
- GTSF1L | c.216G>A p.E72= | Silent (SNP) | VAF 152/612 reads (25%) | called by muse, mutect2, varscan2
- GUCY1A2 | c.1848A>G p.G616= | Silent (SNP) | VAF 102/186 reads (55%) | catalogued as rs1380754600; called by muse, mutect2, varscan2
- GUCY2C | c.783C>T p.D261= | Silent (SNP) | VAF 220/479 reads (46%) | catalogued as rs1320849605, COSV99663708; called by muse, mutect2, varscan2
- H1-10 | c.357G>A p.K119= | Silent (SNP) | VAF 185/528 reads (35%) | called by muse, mutect2, varscan2
- HAND1 | c.456G>A p.K152= | Silent (SNP) | VAF 109/375 reads (29%) | catalogued as CM118979; called by muse, mutect2, varscan2
- HAP1 | c.273G>A p.G91= | Silent (SNP) | VAF 239/674 reads (35%) | called by muse, mutect2, varscan2
- HDAC7 | c.1194C>T p.P398= (on ENST00000427332; = p.P437= on NM_015401.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 123/439 reads (28%) | called by muse, mutect2, varscan2
- HECW1 | c.2691C>T p.S897= | Silent (SNP) | VAF 108/648 reads (17%) | catalogued as rs779152061; called by muse, mutect2, varscan2
- HELZ2 | c.5961C>T p.F1987= (on ENST00000467148 / NM_001037335.2; = p.F1418= on NM_033405.3) | Silent (SNP) | VAF 142/634 reads (22%) | catalogued as COSV71296634; called by muse, mutect2, varscan2
- HEPN1 | c.87G>A p.L29= | Silent (SNP) | VAF 127/267 reads (48%) | catalogued as rs1197784282; called by muse, mutect2, varscan2
- HMGCLL1 | c.222C>T p.L74= | Silent (SNP) | VAF 113/333 reads (34%) | catalogued as COSV51447497; called by muse, mutect2, varscan2
- HNRNPL | c.1551C>T p.F517= | Silent (SNP) | VAF 110/341 reads (32%) | called by muse, mutect2, varscan2
- HPS1 | c.834C>T p.S278= | Silent (SNP) | VAF 150/512 reads (29%) | called by muse, mutect2
- IHH | c.612C>T p.F204= | Silent (SNP) | VAF 171/492 reads (35%) | catalogued as rs750272078; called by muse, mutect2, varscan2
- INTS7 | c.234C>T p.F78= | Silent (SNP) | VAF 52/240 reads (22%) | called by muse, mutect2, varscan2
- ITGA11 | c.1338C>T p.P446= | Silent (SNP) | VAF 199/551 reads (36%) | called by muse, mutect2, varscan2
- ITGAM | c.1458C>T p.T486= | Silent (SNP) | VAF 236/659 reads (36%) | catalogued as rs761646784; called by muse, mutect2, varscan2
- JAKMIP1 | c.2341C>T p.L781= | Silent (SNP) | VAF 121/411 reads (29%) | called by muse, mutect2, varscan2
- JPH4 | c.1045C>T p.L349= | Silent (SNP) | VAF 197/650 reads (30%) | called by muse, mutect2, varscan2
231 further variants in this file (0 protein-altering or splice-affecting, 185 silent, 46 other) are not listed here.
